Somatic mutation profile of tumor specimen 0DE7FL from CCDI case PBBPIX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 11.8 years (4,292 days).
Specimen 0DE7FL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c68ac5a8-6c38-46fa-ba85-9fc6e586add5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE7E1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ce1b5f0-d296-4394-9536-5f5856a6b9de

The open-access MAF lists 17,776 somatic variants for this specimen: 10,538 protein-altering or splice-affecting, 3,915 silent, 3,323 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9,291, Silent 3,915, Intron 1,922, 3'UTR 758, Nonsense Mutation 480, 5'UTR 405, Splice Site 386, Splice Region 275, 5'Flank 87, RNA 86, 3'Flank 64, Frame Shift Ins 52.

Variants (750 of 17,776; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC092143.1 | c.1252G>A p.G418R | Missense Mutation (SNP) | VAF 147/381 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs864321715, CM161051, COSV59247929; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP8B3 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 115/268 reads (43%) | catalogued as rs568761860; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRCA1 | c.4042G>T p.G1348* | Nonsense Mutation (SNP) | VAF 215/493 reads (44%) | catalogued as rs886040191, CD022129; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNGB3 | c.1781+1G>A p.X594_splice | Splice Site (SNP) | VAF 79/207 reads (38%) | catalogued as rs1375507464, CS050784, CS050785; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DDHD2 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 139/496 reads (28%) | catalogued as rs1249841130, COSV68158399; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EVC | c.2446C>T p.Q816* | Nonsense Mutation (SNP) | VAF 79/183 reads (43%) | catalogued as rs374752679; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.7330+1G>A p.X2444_splice | Splice Site (SNP) | VAF 67/135 reads (50%) | catalogued as rs1555394433, CS054896, CS085783; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FKBP10 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 88/227 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs397514674, CM130011, COSV58637640; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FUS | c.1520G>A p.G507D | Missense Mutation (SNP) | VAF 127/291 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as rs267606831, CM101748; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HDAC8 | c.584T>A p.V195D | Missense Mutation (SNP) | VAF 93/115 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1556009247; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NOBOX | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 90/260 reads (35%) | catalogued as rs193303102, CM118409, COSV56196045; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIEZO1 | c.6059C>T p.A2020V | Missense Mutation (SNP) | VAF 68/124 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs587777764, CM135027, COSV56338405; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 96/324 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786204929, CM122894, COSV64288557, COSV64309376; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PTEN | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 146/282 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs397514560, CM1212354, COSV64293891, COSV64295025, COSV64300549; ClinVar: pathogenic; called by muse, varscan2
- RB1 | c.1960+2T>G p.X654_splice | Splice Site (SNP) | VAF 94/128 reads (73%) | hotspot (GDC flag); catalogued as CS145470, COSV57295816, COSV57324879; called by muse, mutect2, varscan2
- SCN5A | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 134/350 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72549410, CM004141; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- STXBP1 | c.707G>A p.G236D | Missense Mutation (SNP) | VAF 151/348 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1554777474; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.643A>G p.S215G | Missense Mutation (SNP) | VAF 101/269 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs886039484, CD1511147, COSV52675946, COSV52689203, COSV52876251, COSV53707934; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 120/302 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555525857, COSV52661319, COSV52679535, COSV53326529; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 116/286 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV50985033; called by muse, mutect2, varscan2
- AACS | c.179A>T p.D60V | Missense Mutation (SNP) | VAF 176/559 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.175); catalogued as rs773709808, COSV99907978; called by muse, mutect2, varscan2
- AADACL4 | c.484C>A p.L162I | Missense Mutation (SNP) | VAF 43/301 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1271721910; called by muse, mutect2, varscan2
- AATK | c.3701T>C p.F1234S (on ENST00000326724 / NM_001080395.3; = p.F1131S on NM_004920.2) | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1471806669; called by muse, varscan2
- ABCA12 | c.6878G>T p.G2293V (on ENST00000272895 / NM_173076.3; = p.G1975V on NM_015657.3) | Missense Mutation (SNP) | VAF 107/287 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55953670; called by muse, mutect2, varscan2
- ABCA13 | c.2406G>A p.W802* | Nonsense Mutation (SNP) | VAF 164/437 reads (38%) | catalogued as COSV70037295, COSV70044261; called by muse, mutect2, varscan2
- ABCA13 | c.3194T>C p.L1065P | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV70025905; called by muse, mutect2, varscan2
- ABCA13 | c.7898A>T p.D2633V | Missense Mutation (SNP) | VAF 122/263 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs367673869; called by muse, mutect2, varscan2
- ABCA13 | c.14579G>A p.G4860E | Missense Mutation (SNP) | VAF 155/361 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1343617695, COSV101291398; called by muse, mutect2, varscan2
- ABCA2 | c.6641C>T p.A2214V (on ENST00000614293; = p.A2184V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/224 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.332); catalogued as rs926082010; called by muse, mutect2, varscan2
- ABCA2 | c.3760C>T p.R1254W (on ENST00000614293; = p.R1224W on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs376060490; called by muse, mutect2, varscan2
- ABCA5 | c.2611A>T p.I871F | Missense Mutation (SNP) | VAF 152/399 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs1364074378; called by muse, mutect2, varscan2
- ABCA5 | c.1812G>A p.M604I | Missense Mutation (SNP) | VAF 130/358 reads (36%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.718); catalogued as rs988079817; called by muse, mutect2, varscan2
- ABCA5 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 94/222 reads (42%) | SIFT tolerated (0.98); PolyPhen benign (0.219); catalogued as rs1381895162, COSV67015782, COSV67019367; called by muse, mutect2, varscan2
- ABCA6 | c.3651G>T p.M1217I | Missense Mutation (SNP) | VAF 191/521 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs1296029373, COSV52638470, COSV52639502; called by muse, mutect2, varscan2
- ABCA6 | c.1181A>G p.Y394C | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as rs878955326; called by muse, mutect2, varscan2
- ABCA8 | c.1009C>T p.L337F | Missense Mutation (SNP) | VAF 164/353 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.364); catalogued as COSV99286545; called by muse, mutect2, varscan2
- ABCB1 | c.2058G>T p.E686D | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV55954768; called by muse, mutect2, varscan2
- ABCB6 | c.1804G>T p.G602W | Missense Mutation (SNP) | VAF 80/186 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV99202396; called by muse, mutect2, varscan2
- ABCC10 | c.1875G>T p.K625N (on ENST00000372530 / NM_001198934.2; = p.K597N on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/308 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs1186969105; called by muse, mutect2, varscan2
- ABCC11 | c.1652G>A p.S551N | Missense Mutation (SNP) | VAF 103/233 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs779531495, COSV62325512; called by muse, mutect2
- ABCC11 | c.657T>A p.S219R | Missense Mutation (SNP) | VAF 101/255 reads (40%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.949); catalogued as COSV100750776; called by muse, mutect2, varscan2
- ABCC3 | c.3874C>T p.R1292W | Missense Mutation (SNP) | VAF 133/285 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as rs772101927; called by muse, mutect2, varscan2
- ABCC8 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 171/391 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs577545383, COSV56849292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCD2 | c.1924G>T p.D642Y | Missense Mutation (SNP) | VAF 16/376 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100429534; called by muse, mutect2
- ABCF2 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 28/608 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55182275; called by muse, mutect2
- ABHD6 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 96/275 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.072); catalogued as rs1417377125; called by muse, varscan2
- ABI1 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 96/268 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs750066446; called by muse, mutect2, varscan2
- ABI1 | c.901+1G>A p.X301_splice | Splice Site (SNP) | VAF 129/319 reads (40%) | catalogued as COSV61016186; called by muse, mutect2, varscan2
- ABI3BP | c.1625G>A p.R542H | Missense Mutation (SNP) | VAF 172/434 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs202241381; called by muse, varscan2
- ABRAXAS2 | c.577G>A p.G193S | Missense Mutation (SNP) | VAF 108/254 reads (43%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.797); catalogued as COSV53716726; called by muse, mutect2, varscan2
- AC004997.1 | c.974C>T p.T325M | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT deleterious, low confidence (0); catalogued as rs749659130, COSV99042475; called by muse, mutect2, varscan2
- AC005324.2 | c.1223T>C p.L408P | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.748); catalogued as rs764285410; called by muse, mutect2, varscan2
- AC006059.2 | c.2171G>A p.S724N | Missense Mutation (SNP) | VAF 82/203 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.131); catalogued as rs772864738; called by muse, mutect2, varscan2
- AC098582.1 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 77/358 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52017703; called by muse, mutect2, varscan2
- AC139530.2 | c.76C>T p.R26* | Nonsense Mutation (SNP) | VAF 106/233 reads (45%) | catalogued as rs1214696093; called by muse, mutect2, varscan2
- ACACA | c.7118G>A p.R2373Q | Missense Mutation (SNP) | VAF 128/296 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs773877053; called by muse, mutect2, varscan2
- ACAP3 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 82/300 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs750225557; called by muse, mutect2, varscan2
- ACAT1 | c.579+7G>A | Splice Region (SNP) | VAF 42/130 reads (32%) | catalogued as rs1487734239; called by muse, varscan2
- ACBD5 | c.963G>T p.E321D (on ENST00000375888 / NM_001352568.1; = p.E312D on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 125/310 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as COSV65520626; called by muse, mutect2, varscan2
- ACCSL | c.724T>C p.C242R | Missense Mutation (SNP) | VAF 141/376 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs751488903; called by muse, mutect2, varscan2
- ACE2 | c.2078A>G p.D693G | Missense Mutation (SNP) | VAF 157/201 reads (78%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); catalogued as rs781544129; called by muse, mutect2, varscan2
- ACE2 | c.595T>C p.Y199H | Missense Mutation (SNP) | VAF 134/160 reads (84%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.52); catalogued as rs1277079227; called by muse, mutect2, varscan2
- ACER1 | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV100033856; called by muse, mutect2, varscan2
- ACHE | c.1141A>G p.N381D | Missense Mutation (SNP) | VAF 106/286 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as rs769216259, COSV53816286; called by muse, mutect2, varscan2
- ACHE | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 91/314 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.43); catalogued as COSV53819130; called by muse, mutect2, varscan2
- ACIN1 | c.3775G>T p.E1259* | Nonsense Mutation (SNP) | VAF 175/436 reads (40%) | catalogued as COSV52976248; called by muse, mutect2, varscan2
- ACIN1 | c.3487C>T p.R1163C | Missense Mutation (SNP) | VAF 23/384 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as rs1159894752; called by muse, mutect2
- ACIN1 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 117/306 reads (38%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs138922311; called by muse, mutect2, varscan2
- ACO2 | c.11A>G p.Y4C | Missense Mutation (SNP) | VAF 110/241 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.155); catalogued as rs1432057983, COSV53440450; called by muse, mutect2, varscan2
- ACP3 | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 81/216 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV60485928; called by muse, mutect2, varscan2
- ACP3 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 185/498 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV60488889; called by muse, mutect2, varscan2
- ACSBG1 | c.1393G>A p.G465S | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV51906088; called by muse, mutect2, varscan2
- ACSL6 | c.877G>A p.V293M (on ENST00000379240; = p.V318M on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 174/434 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.18); catalogued as rs375566990; called by muse, mutect2, varscan2
- ACTG1 | c.565C>T p.L189F | Missense Mutation (SNP) | VAF 41/248 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.993); catalogued as rs781827845; called by muse, mutect2, varscan2
- ACTN1 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 135/331 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as rs1179212172, COSV99518375; called by muse, varscan2
- ACTN4 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 146/309 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs767795519, COSV53149909; called by muse, mutect2, varscan2
- ACTR5 | c.1261C>A p.P421T | Missense Mutation (SNP) | VAF 100/332 reads (30%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.726); catalogued as rs959152053; called by muse, varscan2
- ACTRT1 | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 112/137 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1235343335, COSV100947725; called by muse, mutect2, varscan2
- ADAM2 | c.2145dup p.W716Mfs*4 | Frame Shift Ins (INS) | VAF 41/249 reads (16%) | catalogued as rs764499662; called by mutect2, varscan2
- ADAM20 | c.1999G>T p.G667C | Missense Mutation (SNP) | VAF 110/283 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1457134533; called by muse, varscan2
- ADAM28 | c.312T>A p.D104E | Missense Mutation (SNP) | VAF 128/350 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.251); catalogued as COSV56101759; called by muse, mutect2, varscan2
- ADAM29 | c.669G>T p.E223D | Missense Mutation (SNP) | VAF 114/266 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV63660685; called by mutect2, varscan2
- ADAM8 | c.1739C>T p.T580I | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as rs993675416, COSV69865380; called by muse, mutect2, varscan2
- ADAM8 | c.1285-8C>T | Splice Region (SNP) | VAF 40/109 reads (37%) | catalogued as rs1334918630; called by muse, mutect2, varscan2
- ADAMDEC1 | c.281C>A p.T94N | Missense Mutation (SNP) | VAF 97/272 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs745572485, COSV56477622; called by mutect2, varscan2
- ADAMTS16 | c.2023G>T p.D675Y | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV56986396; called by muse, mutect2, varscan2
- ADAMTS20 | c.3970C>A p.L1324I | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as rs1173626689; called by muse, mutect2, varscan2
- ADAMTS20 | c.3264C>T p.C1088= | Splice Region (SNP) | VAF 63/252 reads (25%) | catalogued as rs748773695; called by muse, mutect2, varscan2
- ADAMTS9 | c.2957C>T p.P986L | Missense Mutation (SNP) | VAF 137/351 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55779958; called by muse, mutect2, varscan2
- ADAMTSL1 | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.621); catalogued as COSV52816905, COSV99440721; called by muse, mutect2, varscan2
- ADAP1 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 115/268 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776696929; called by muse, mutect2, varscan2
- ADCY10 | c.1420G>T p.A474S | Missense Mutation (SNP) | VAF 132/338 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.056); catalogued as COSV63244523; called by muse, mutect2, varscan2
- ADCY10 | c.680A>T p.D227V | Missense Mutation (SNP) | VAF 150/348 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV63239615; called by muse, mutect2, varscan2
- ADGRB3 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV65422673; called by muse, mutect2, varscan2
- ADGRB3 | c.2927C>T p.T976I | Missense Mutation (SNP) | VAF 135/344 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV53260113; called by muse, mutect2, varscan2
- ADGRL2 | c.3312C>A p.C1104* (on ENST00000370717 / NM_001366005.1; = p.C1091* on NM_012302.4) | Nonsense Mutation (SNP) | VAF 72/164 reads (44%) | catalogued as COSV99586950; called by muse, varscan2
- ADGRL3 | c.1887G>T p.K629N (on ENST00000506720 / NM_001322402.2; = p.K561N on NM_015236.6) | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV72230417, COSV72230467; called by muse, mutect2, varscan2
- ADGRV1 | c.15205C>A p.Q5069K | Missense Mutation (SNP) | VAF 110/311 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV67989948; called by muse, mutect2, varscan2
- ADH1B | c.401G>A p.R134K | Missense Mutation (SNP) | VAF 94/182 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV59296649; called by muse, varscan2
- ADH1C | c.744G>T p.K248N | Missense Mutation (SNP) | VAF 132/346 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV72463375; called by muse, mutect2, varscan2
- ADNP | c.2246C>T p.P749L | Missense Mutation (SNP) | VAF 85/301 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.792); catalogued as rs546813939; called by muse, mutect2, varscan2
- ADPRM | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 147/430 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.627); catalogued as rs199523732; called by muse, varscan2
- ADSS2 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 176/436 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs749735276, COSV63694895; called by muse, mutect2, varscan2
- AFDN | c.2015G>A p.S672N | Missense Mutation (SNP) | VAF 83/222 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs903533399; called by muse, mutect2, varscan2
- AFF2 | c.2777G>T p.R926L | Missense Mutation (SNP) | VAF 140/162 reads (86%) | SIFT tolerated (0.33); PolyPhen benign (0.282); catalogued as COSV53987532, COSV54007591; called by muse, varscan2
- AFF3 | c.1595G>T p.R532M | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57869814; called by muse, mutect2, varscan2
- AFG3L2 | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 88/260 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.045); catalogued as COSV52314020; called by muse, varscan2
- AGAP5 | c.1409T>A p.I470N | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1439175423; called by muse, mutect2, varscan2
- AGO1 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs1196584082, COSV100940788; called by muse, mutect2, varscan2
- AGRN | c.4097G>A p.C1366Y | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769252195; called by muse, mutect2, varscan2
- AGTPBP1 | c.1856C>T p.P619L (on ENST00000357081 / NM_001330701.2; = p.P579L on NM_015239.2) | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as rs751120221; called by muse, mutect2, varscan2
- AHCTF1 | c.6164T>A p.V2055D (on ENST00000366508; = p.V2029D on NM_015446.5) | Missense Mutation (SNP) | VAF 137/402 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as COSV58253200, COSV58253290; called by muse, mutect2, varscan2
- AHCTF1 | c.1910-1G>A p.X637_splice (on ENST00000366508; = p.X611_splice on NM_015446.5) | Splice Site (SNP) | VAF 91/232 reads (39%) | catalogued as COSV100403176; called by muse, mutect2, varscan2
- AHCTF1 | c.1481T>C p.V494A (on ENST00000366508; = p.V468A on NM_015446.5) | Missense Mutation (SNP) | VAF 18/249 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.218); catalogued as COSV100403274; called by muse, mutect2
- AHDC1 | c.2798C>T p.P933L | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.327); catalogued as rs1369541471; called by muse, mutect2, varscan2
- AHI1 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 160/374 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1196560196; called by muse, mutect2, varscan2
- AHNAK | c.12168G>T p.W4056C | Missense Mutation (SNP) | VAF 123/284 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs747005304, COSV99948519; called by muse, mutect2, varscan2
- AHNAK | c.5562G>T p.K1854N | Missense Mutation (SNP) | VAF 138/412 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as COSV57202283, COSV57212409; called by muse, mutect2, varscan2
- AHNAK2 | c.4445C>T p.A1482V | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs1309430931; called by muse, varscan2
- AHNAK2 | c.2483C>T p.A828V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV60908971; called by muse, mutect2, varscan2
- AHRR | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 88/193 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs546650499, COSV57087562; called by muse, mutect2, varscan2
- AHRR | c.1774C>T p.R592W | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs370481942; called by mutect2, varscan2
- AIP | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 62/220 reads (28%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.733); catalogued as rs61741147; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AK5 | c.950A>G p.N317S (on ENST00000354567 / NM_174858.3; = p.N291S on NM_012093.4) | Missense Mutation (SNP) | VAF 107/278 reads (38%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs764264023; called by muse, mutect2, varscan2
- AK7 | c.1886G>A p.R629Q | Missense Mutation (SNP) | VAF 148/332 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as rs746706465, COSV99967045; called by muse, varscan2
- AKAP10 | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 171/397 reads (43%) | catalogued as rs750037851; called by muse, mutect2, varscan2
- AKAP6 | c.3835G>T p.A1279S | Missense Mutation (SNP) | VAF 102/245 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0.014); catalogued as COSV99797862; called by muse, mutect2, varscan2
- AKAP6 | c.5039T>A p.I1680N | Missense Mutation (SNP) | VAF 95/250 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs113195718; called by muse, mutect2, varscan2
- AKNAD1 | c.1269C>A p.H423Q | Missense Mutation (SNP) | VAF 123/328 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs112398173; called by muse, mutect2, varscan2
- AKR1C1 | c.566A>T p.N189I | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66498962; called by muse, mutect2, varscan2
- AKR1C4 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 102/266 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as rs529198618, COSV54125324; called by muse, mutect2, varscan2
- AKR1E2 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 79/250 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as COSV53629601; called by muse, mutect2, varscan2
- AKR1E2 | c.880C>T p.L294F | Missense Mutation (SNP) | VAF 28/285 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.443); catalogued as rs954057217; called by muse, mutect2, varscan2
- AL031178.1 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); catalogued as rs753592574; called by muse, mutect2, varscan2
- ALAS1 | c.1879T>A p.S627T | Missense Mutation (SNP) | VAF 118/292 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as rs1356566824; called by muse, varscan2
- ALDH16A1 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1271033907, COSV99513017; called by muse, mutect2
- ALDH16A1 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 127/317 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV53193244; called by muse, mutect2, varscan2
- ALDH3B2 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs149110344; called by muse, mutect2, varscan2
- ALDH4A1 | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs759758353, COSV51890148; called by muse, mutect2, varscan2
- ALDH7A1 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 96/249 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as rs771975420, COSV63160888; called by muse, mutect2, varscan2
- ALK | c.4222G>A p.E1408K | Missense Mutation (SNP) | VAF 108/358 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs145600484; called by muse, mutect2, varscan2
- ALK | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 152/382 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1489798954; called by muse, mutect2, varscan2
- ALKAL2 | c.307+1G>A p.X103_splice | Splice Site (SNP) | VAF 22/404 reads (5%) | catalogued as rs1450117012; called by muse, mutect2
- ALKBH8 | c.772-1G>A p.X258_splice | Splice Site (SNP) | VAF 145/341 reads (43%) | catalogued as rs142835708; called by muse, mutect2, varscan2
- ALKBH8 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 87/245 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52834384; called by muse, mutect2, varscan2
- ALMS1 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 88/164 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); catalogued as COSV52504085; called by muse, mutect2, varscan2
- ALMS1 | c.4084G>T p.V1362F | Missense Mutation (SNP) | VAF 146/332 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs534858351, COSV52523917; called by muse, mutect2, varscan2
- ALOX5 | c.1586C>T p.S529L | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV65551304, COSV65552070; called by muse, mutect2, varscan2
- ALPK1 | c.499A>G p.I167V | Missense Mutation (SNP) | VAF 100/359 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as rs1349665138; called by muse, mutect2, varscan2
- ALPK3 | c.3907A>G p.S1303G | Missense Mutation (SNP) | VAF 96/302 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as rs1358746027; called by muse, mutect2, varscan2
- ALPP | c.725A>T p.D242V | Missense Mutation (SNP) | VAF 111/334 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.604); catalogued as COSV101235213; called by muse, mutect2, varscan2
- ALS2 | c.538T>A p.L180M | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV99968915; called by muse, mutect2, varscan2
- ALX1 | c.269C>G p.T90S | Missense Mutation (SNP) | VAF 68/264 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.341); catalogued as COSV57492853; called by muse, varscan2
- AMPD1 | c.2295G>A p.W765* | Nonsense Mutation (SNP) | VAF 111/303 reads (37%) | catalogued as rs1467664203; called by muse, mutect2, varscan2
- AMPH | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 100/264 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as rs1338903221, COSV100340408; called by muse, mutect2, varscan2
- AMPH | c.70-1G>A p.X24_splice | Splice Site (SNP) | VAF 26/275 reads (9%) | catalogued as COSV57742127; called by muse, mutect2
- AMY2B | c.904A>T p.M302L | Missense Mutation (SNP) | VAF 77/210 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs906883671, COSV63717088; called by muse, mutect2, varscan2
- ANAPC2 | c.1915C>T p.H639Y | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs767211802; called by muse, mutect2, varscan2
- ANK2 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52180788; called by muse, mutect2
- ANK3 | c.5227G>A p.E1743K | Missense Mutation (SNP) | VAF 96/227 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as COSV55073952; called by muse, mutect2, varscan2
- ANKAR | c.3021G>A p.M1007I | Missense Mutation (SNP) | VAF 98/247 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs953264593; called by muse, mutect2, varscan2
- ANKAR | c.4202C>T p.T1401I | Missense Mutation (SNP) | VAF 103/267 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs1366675991; called by muse, mutect2, varscan2
- ANKEF1 | c.317A>G p.D106G | Missense Mutation (SNP) | VAF 72/234 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs368975724; called by muse, mutect2, varscan2
- ANKEF1 | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 154/375 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs747097642, COSV65694047; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2321C>A p.P774H | Missense Mutation (SNP) | VAF 136/404 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as rs761333682; called by muse, mutect2, varscan2
- ANKLE1 | c.1896G>A p.W632* (on ENST00000394458; = p.W578* on NM_152363.6) | Nonsense Mutation (SNP) | VAF 92/215 reads (43%) | catalogued as rs1187453165; called by muse, mutect2, varscan2
- ANKLE2 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 234/488 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as rs201575018, COSV100514308; called by muse, mutect2, varscan2
- ANKMY1 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs201252509, COSV56036648; called by muse, mutect2, varscan2
- ANKRD13A | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 136/382 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs749046410; called by muse, varscan2
- ANKRD26 | c.5028A>G p.I1676M | Missense Mutation (SNP) | VAF 101/307 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.096); catalogued as COSV101063503; called by muse, mutect2, varscan2
- ANKRD26 | c.4513G>A p.A1505T | Missense Mutation (SNP) | VAF 100/262 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1409346040; called by muse, mutect2, varscan2
- ANKRD30A | c.1219A>T p.T407S (on ENST00000611781; = p.T351S on NM_052997.2) | Missense Mutation (SNP) | VAF 158/360 reads (44%) | SIFT tolerated (0.87); PolyPhen benign (0.292); catalogued as rs771060239; called by muse, mutect2, varscan2
- ANKRD31 | c.4780C>A p.L1594I | Missense Mutation (SNP) | VAF 133/337 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.954); catalogued as COSV57159205; called by muse, mutect2, varscan2
- ANKRD34B | c.1142C>A p.P381H | Missense Mutation (SNP) | VAF 98/233 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as rs763836907; called by muse, mutect2, varscan2
- ANKRD34B | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 82/203 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as rs376632230; called by muse, mutect2, varscan2
- ANKRD35 | c.2155C>T p.Q719* | Nonsense Mutation (SNP) | VAF 106/278 reads (38%) | catalogued as rs372205611; called by muse, mutect2
- ANKRD36 | c.1727C>A p.S576Y | Missense Mutation (SNP) | VAF 112/318 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs754950741; called by muse, mutect2, varscan2
- ANKRD50 | c.2182G>A p.A728T | Missense Mutation (SNP) | VAF 129/166 reads (78%) | SIFT tolerated (0.31); PolyPhen benign (0.073); catalogued as rs377077898; called by muse, mutect2, varscan2
- ANKRD55 | c.1375C>A p.L459M | Missense Mutation (SNP) | VAF 78/201 reads (39%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.215); catalogued as COSV100591568; called by muse, mutect2, varscan2
- ANKRD65 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1449350446; called by muse, varscan2
- ANKS3 | c.1033C>A p.L345M | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.365); catalogued as rs1405295973; called by muse, mutect2, varscan2
- ANKS4B | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 192/466 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV100289784; called by muse, mutect2, varscan2
- ANO8 | c.2799G>T p.E933D | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.935); catalogued as COSV99344677; called by muse, mutect2, varscan2
- ANPEP | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 74/168 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs367926309; called by muse, mutect2, varscan2
- ANXA7 | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 82/237 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV100873481; called by muse, mutect2, varscan2
- ANXA9 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 156/414 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.325); catalogued as rs1223091337; called by muse, mutect2, varscan2
- AOC3 | c.70C>A p.L24M | Missense Mutation (SNP) | VAF 162/359 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV53828806; called by muse, mutect2, varscan2
- AOC3 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 123/284 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as rs781215948, COSV53826712; called by muse, mutect2, varscan2
- AOC3 | c.1840C>T p.P614S | Missense Mutation (SNP) | VAF 139/335 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.12); catalogued as COSV53828422; called by muse, mutect2, varscan2
- AP002748.5 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as rs763004810, COSV59152621; ClinVar: uncertain significance; called by muse, varscan2
- AP1M1 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52229136; called by muse, mutect2, varscan2
- AP2S1 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 131/341 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1057522809, COSV54383650; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP3B1 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 102/311 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1456578906; called by muse, mutect2, varscan2
- AP3D1 | c.2005C>T p.R669* | Nonsense Mutation (SNP) | VAF 47/102 reads (46%) | catalogued as COSV61430783; called by muse, varscan2
- APBA1 | c.1271C>A p.P424H | Missense Mutation (SNP) | VAF 126/313 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV99597329; called by muse, mutect2, varscan2
- APC | c.1052G>T p.G351V | Missense Mutation (SNP) | VAF 102/250 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99969111; called by muse, mutect2, varscan2
- APC | c.7078G>T p.G2360C | Missense Mutation (SNP) | VAF 132/326 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV99967740; called by muse, mutect2, varscan2
- APH1A | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 141/467 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs1480306411; called by muse, mutect2, varscan2
- APLP2 | c.1340G>A p.S447N | Missense Mutation (SNP) | VAF 136/305 reads (45%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as rs200359846; called by muse, mutect2, varscan2
- APOBEC3A | c.137T>A p.V46D | Missense Mutation (SNP) | VAF 99/230 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV50779913; called by muse, mutect2, varscan2
- APOBEC3F | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 78/453 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1424009154, COSV100415147; called by muse, mutect2, varscan2
- APOBEC3H | c.*35-1G>T | Splice Site (SNP) | VAF 87/252 reads (35%) | catalogued as COSV62378556; called by muse, mutect2
- APOL6 | c.891G>T p.R297S | Missense Mutation (SNP) | VAF 238/380 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as rs200252501; called by muse, mutect2, varscan2
- APOOL | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 134/179 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762864062, COSV100920821; called by muse, varscan2
- ARF3 | c.332T>C p.L111P | Missense Mutation (SNP) | VAF 125/296 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.929); catalogued as rs1371506588; called by muse, mutect2, varscan2
- ARFIP1 | c.850G>A p.A284T (on ENST00000353617 / NM_001287432.1; = p.A252T on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 187/380 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs752375327; called by muse, mutect2, varscan2
- ARGFX | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 84/204 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs763603983; called by muse, mutect2, varscan2
- ARHGAP1 | c.680C>A p.A227D | Missense Mutation (SNP) | VAF 144/346 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as rs781348427; called by muse, mutect2, varscan2
- ARHGAP10 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 116/155 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs1057432168; called by muse, mutect2, varscan2
- ARHGAP10 | c.2353C>A p.L785M | Missense Mutation (SNP) | VAF 91/191 reads (48%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.627); catalogued as rs1336585626; called by muse, mutect2, varscan2
- ARHGAP11A | c.814T>C p.Y272H | Missense Mutation (SNP) | VAF 134/325 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1348634002; called by muse, mutect2, varscan2
- ARHGAP15 | c.959G>A p.G320D | Missense Mutation (SNP) | VAF 122/368 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1191116979, COSV99713639; called by muse, mutect2, varscan2
- ARHGAP20 | c.3266A>G p.E1089G | Missense Mutation (SNP) | VAF 79/180 reads (44%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as rs780300469; called by muse, mutect2, varscan2
- ARHGAP22 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140701623; called by muse, mutect2, varscan2
- ARHGAP27 | c.1855C>T p.P619S (on ENST00000428638 / NM_001282290.1; = p.P278S on NM_199282.3) | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as rs555938540; called by muse, varscan2
- ARHGAP29 | c.718A>G p.M240V | Missense Mutation (SNP) | VAF 46/497 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1487401928; called by muse, mutect2
- ARHGAP32 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 84/233 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1348521078; called by muse, mutect2, varscan2
- ARHGEF12 | c.1796G>A p.S599N | Missense Mutation (SNP) | VAF 166/372 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV100754776; called by muse, mutect2, varscan2
- ARHGEF12 | c.2740G>A p.D914N | Missense Mutation (SNP) | VAF 100/249 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV63106910; called by muse, mutect2, varscan2
- ARHGEF16 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 94/225 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1012460755; called by muse, mutect2, varscan2
- ARHGEF2 | c.481G>A p.D161N (on ENST00000361247 / NM_001162383.2; = p.D134N on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs985840732, COSV99047303; called by muse, varscan2
- ARHGEF28 | c.1043T>C p.L348P | Missense Mutation (SNP) | VAF 158/504 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.863); catalogued as rs757055413; called by muse, mutect2, varscan2
- ARHGEF28 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 105/233 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.026); catalogued as COSV55249910; called by muse, mutect2, varscan2
- ARHGEF40 | c.2929G>A p.G977R | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs780548792; called by muse, varscan2
- ARHGEF40 | c.2972C>T p.S991F | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.456); catalogued as rs1167118016, COSV53880017; called by muse, varscan2
- ARHGEF5 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 70/766 reads (9%) | catalogued as rs539904703; called by muse, varscan2
- ARID1A | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as rs890504620; called by muse, mutect2, varscan2
- ARID1B | c.1762G>A p.G588S | Missense Mutation (SNP) | VAF 89/243 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1349709189, COSV51677672; called by muse, mutect2, varscan2
- ARID1B | c.2986G>T p.A996S | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.444); catalogued as COSV51649650; called by muse, mutect2, varscan2
- ARID3A | c.1594+4G>A | Splice Region (SNP) | VAF 34/100 reads (34%) | catalogued as rs1468745778; called by muse, mutect2, varscan2
- ARID3B | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 52/312 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs200098384; called by muse, mutect2, varscan2
- ARID4A | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 144/385 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV104415573; called by muse, mutect2, varscan2
- ARID5B | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 112/269 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as rs543501415; called by muse, mutect2, varscan2
- ARL14EP | c.164C>T p.T55I | Missense Mutation (SNP) | VAF 23/442 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV56342627; called by muse, mutect2
- ARMC2 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 77/183 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs200354649; called by muse, mutect2, varscan2
- ARMH3 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 116/250 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as rs1166727218; called by muse, mutect2, varscan2
- ARNT | c.1663C>A p.P555T | Missense Mutation (SNP) | VAF 104/265 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV62230187; called by muse, mutect2, varscan2
- ARPP21 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs535145550, COSV51792286, COSV51800995; called by muse, varscan2
- ARSF | c.1102+2T>C p.X368_splice | Splice Site (SNP) | VAF 72/80 reads (90%) | catalogued as COSV63840335; called by muse, mutect2, varscan2
- ARSJ | c.1736dup p.K580Efs*32 | Frame Shift Ins (INS) | VAF 122/347 reads (35%) | catalogued as rs753865255; called by mutect2, varscan2
- ART1 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 122/334 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1476619791; called by muse, varscan2
- ASAP1 | c.1270C>A p.R424S | Missense Mutation (SNP) | VAF 140/370 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs565525997, COSV63056052; called by muse, mutect2, varscan2
- ASAP1 | c.313A>T p.N105Y | Missense Mutation (SNP) | VAF 161/397 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63053644; called by muse, mutect2, varscan2
- ASAP2 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 146/388 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs761463891; called by muse, mutect2, varscan2
- ASB15 | c.1096A>G p.T366A | Missense Mutation (SNP) | VAF 68/239 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.204); catalogued as rs746401462; called by muse, mutect2, varscan2
- ASB3 | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 108/234 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs750944749; called by muse, mutect2, varscan2
- ASB4 | c.65T>C p.L22P | Missense Mutation (SNP) | VAF 166/414 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1412028148; called by muse, mutect2, varscan2
- ASH2L | c.1453G>A p.V485I | Missense Mutation (SNP) | VAF 124/340 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs767918385, COSV51699794; called by muse, mutect2, varscan2
- ASPH | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as COSV62862054; called by muse, mutect2, varscan2
- ASTE1 | c.1040T>A p.V347D | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1443074102; called by muse, mutect2, varscan2
- ASTN1 | c.2073G>T p.K691N | Missense Mutation (SNP) | VAF 144/359 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV56070898; called by muse, mutect2, varscan2
- ASXL3 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 128/360 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52474715; called by muse, mutect2, varscan2
- ASXL3 | c.6041T>C p.L2014P | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.819); catalogued as rs766886126; called by muse, mutect2, varscan2
- ATAD2 | c.1049+2T>A p.X350_splice | Splice Site (SNP) | VAF 115/268 reads (43%) | catalogued as COSV54881698; called by muse, mutect2, varscan2
- ATG16L2 | c.899G>A p.R300K | Missense Mutation (SNP) | VAF 137/333 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.677); catalogued as rs749372930, COSV58361622; called by muse, mutect2, varscan2
- ATIC | c.931A>G p.R311G | Missense Mutation (SNP) | VAF 106/246 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99378269; called by muse, mutect2, varscan2
- ATM | c.497-2A>G p.X166_splice | Splice Site (SNP) | VAF 78/198 reads (39%) | catalogued as rs1278985870; called by muse, mutect2, varscan2
- ATM | c.4028T>C p.I1343T | Missense Mutation (SNP) | VAF 130/339 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1309605588; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATMIN | c.80C>T p.T27I | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1307067491; called by muse, mutect2, varscan2
- ATP10A | c.4021G>A p.G1341R | Missense Mutation (SNP) | VAF 124/298 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs200297626; called by muse, mutect2, varscan2
- ATP11A | c.3017C>T p.T1006M | Missense Mutation (SNP) | VAF 137/196 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as rs551993113, COSV52105821; called by muse, mutect2
- ATP11B | c.3386C>T p.A1129V | Missense Mutation (SNP) | VAF 146/325 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); catalogued as rs777176110, COSV100017680; called by muse, mutect2, varscan2
- ATP1B1 | c.363G>T p.M121I | Missense Mutation (SNP) | VAF 74/301 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1285880653; called by muse, varscan2
- ATP2B4 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 103/282 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs754998537; called by muse, mutect2, varscan2
- ATP5F1B | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 131/355 reads (37%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.022); catalogued as rs1399968530; called by muse, mutect2, varscan2
- ATP5MF | c.258G>A p.K86= | Splice Region (SNP) | VAF 21/329 reads (6%) | catalogued as COSV52854008; called by muse, mutect2
- ATP6V0A2 | c.2571A>G p.*857Wext*38 | Nonstop Mutation (SNP) | VAF 262/490 reads (53%) | catalogued as rs1234905832; called by muse, varscan2
- ATP7B | c.2663C>T p.T888I | Missense Mutation (SNP) | VAF 35/236 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs935426164; called by muse, mutect2, varscan2
- ATP8A2 | c.216G>T p.Q72H | Missense Mutation (SNP) | VAF 155/204 reads (76%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747042311; called by muse, mutect2, varscan2
- ATP8B1 | c.353G>T p.R118I | Missense Mutation (SNP) | VAF 150/384 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52176290; called by muse, mutect2, varscan2
- ATP8B2 | c.122G>T p.R41L (on ENST00000672630; = p.R8L on NM_001005855.2) | Missense Mutation (SNP) | VAF 166/372 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.097); catalogued as rs1291502459, COSV59244814; called by muse, mutect2, varscan2
- ATP8B4 | c.2476G>A p.A826T | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs368776149; called by muse, mutect2, varscan2
- ATP9A | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 75/181 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100124323; called by muse, mutect2, varscan2
- ATP9B | c.1811C>T p.T604M | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs377539032; called by muse, mutect2, varscan2
- ATP9B | c.2611G>A p.A871T | Missense Mutation (SNP) | VAF 85/229 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs754617060; called by muse, mutect2, varscan2
- ATR | c.5321G>A p.R1774K | Missense Mutation (SNP) | VAF 27/518 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV63390073; called by muse, mutect2
- ATRX | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 108/131 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1557140467, COSV64885273; called by muse, mutect2, varscan2
- ATXN2 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as rs1249404558; called by muse, mutect2, varscan2
- ATXN3 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 154/390 reads (39%) | catalogued as rs1300135703, COSV61494532; called by muse, mutect2, varscan2
- ATXN7L3 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 93/254 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101231725; called by muse, mutect2, varscan2
- B4GALNT2 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 83/217 reads (38%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.019); catalogued as rs1341812825; called by muse, mutect2, varscan2
- B4GALT3 | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 99/268 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1175026048; called by muse, mutect2, varscan2
- BAG3 | c.423G>A p.M141I | Missense Mutation (SNP) | VAF 84/206 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV64841876; called by muse, mutect2, varscan2
- BAG6 | c.1661G>T p.R554L (on ENST00000676571; = p.R507L on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/381 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.958); catalogued as COSV52987683; called by muse, mutect2
- BAHCC1 | c.6685G>A p.G2229R | Missense Mutation (SNP) | VAF 104/253 reads (41%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.586); catalogued as rs1464907862; called by muse, mutect2, varscan2
- BAIAP2L2 | c.1003C>T p.H335Y | Missense Mutation (SNP) | VAF 87/159 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs769089800, COSV101092135; called by muse, varscan2
- BAIAP2L2 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as rs1035677770; called by muse, mutect2, varscan2
- BAIAP3 | c.1910G>A p.R637H | Missense Mutation (SNP) | VAF 86/233 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs373118062; called by muse, mutect2, varscan2
- BAIAP3 | c.3125C>T p.A1042V | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs1363717963; called by muse, mutect2, varscan2
- BAP1 | c.1943C>T p.A648V | Missense Mutation (SNP) | VAF 106/274 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.033); catalogued as rs755915077; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAP1 | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 86/267 reads (32%) | catalogued as COSV56231807; called by muse, varscan2
- BAZ1B | c.693G>T p.K231N | Missense Mutation (SNP) | VAF 141/325 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV59993205; called by muse, mutect2, varscan2
- BAZ2A | c.3251C>T p.P1084L | Missense Mutation (SNP) | VAF 33/434 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV99464773; called by muse, mutect2
- BBX | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 143/341 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV57887134; called by muse, mutect2, varscan2
- BCAR1 | c.241A>G p.T81A | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV50787107; called by muse, mutect2, varscan2
- BCAR1 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 130/299 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1254070834; called by muse, mutect2, varscan2
- BCHE | c.98T>C p.I33T | Missense Mutation (SNP) | VAF 144/312 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.348); catalogued as rs748604050, CD973664; called by muse, mutect2, varscan2
- BCL2L12 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1372728241; called by muse, mutect2, varscan2
- BCL7C | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 73/135 reads (54%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs746313841, COSV100979697; called by muse, mutect2, varscan2
- BCOR | c.1976C>T p.P659L | Missense Mutation (SNP) | VAF 71/81 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100652833; called by muse, mutect2, varscan2
- BCOR | c.1612C>T p.Q538* | Nonsense Mutation (SNP) | VAF 104/121 reads (86%) | catalogued as COSV100653124; called by muse, varscan2
- BFSP2 | c.23T>C p.V8A | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as rs1179778800; called by muse, mutect2, varscan2
- BHLHE41 | c.476G>A p.C159Y | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); catalogued as rs1362880398; called by muse, mutect2, varscan2
- BICRA | c.4162C>T p.R1388C | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV101194492; called by muse, mutect2, varscan2
- BIN2 | c.217G>T p.V73L | Missense Mutation (SNP) | VAF 76/252 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.346); catalogued as rs1161982744; called by muse, varscan2
- BIRC2 | c.1021G>A p.G341S | Missense Mutation (SNP) | VAF 164/352 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143612582; called by muse, mutect2, varscan2
- BIRC2 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 85/296 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV57162247; called by muse, mutect2, varscan2
- BIRC3 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 158/539 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54820575; called by muse, mutect2, varscan2
- BIRC6 | c.9704G>A p.C3235Y | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101429353, COSV70204584; called by muse, mutect2, varscan2
- BIRC6 | c.13921C>T p.P4641S | Missense Mutation (SNP) | VAF 149/364 reads (41%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.996); catalogued as COSV101428224; called by muse, mutect2, varscan2
- BIRC6 | c.14067G>T p.L4689F | Missense Mutation (SNP) | VAF 152/324 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70196178; called by muse, varscan2
- BLNK | c.103A>G p.K35E | Missense Mutation (SNP) | VAF 93/270 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV56410883; called by muse, mutect2, varscan2
- BMP2K | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 135/310 reads (44%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs780640612, COSV58592648; called by muse, mutect2, varscan2
- BMPR1A | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 125/352 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs771452619, COSV64405729; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMX | c.1020-2A>G p.X340_splice | Splice Site (SNP) | VAF 58/69 reads (84%) | catalogued as rs1026001410; called by muse, mutect2, varscan2
- BOD1L1 | c.8698G>A p.V2900I | Missense Mutation (SNP) | VAF 37/401 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV99240083; called by muse, mutect2
- BOD1L1 | c.1915C>T p.H639Y | Missense Mutation (SNP) | VAF 117/325 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs1267683650; called by muse, mutect2, varscan2
- BPIFB6 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs1295466418; called by muse, mutect2, varscan2
- BPNT1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 148/361 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as rs753054605, COSV59040605; called by muse, mutect2, varscan2
- BPTF | c.7403G>A p.R2468H | Missense Mutation (SNP) | VAF 178/369 reads (48%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.374); catalogued as rs910602094, COSV100076081; called by muse, mutect2, varscan2
- BRCA1 | c.3094A>G p.R1032G | Missense Mutation (SNP) | VAF 164/418 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as CD076748; called by muse, mutect2
- BRCA2 | c.7141C>T p.P2381S | Missense Mutation (SNP) | VAF 237/319 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs777305503, COSV66449433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD4 | c.3709C>T p.R1237C | Missense Mutation (SNP) | VAF 85/194 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54586784, COSV54596856; called by muse, mutect2, varscan2
- BRD4 | c.1847G>A p.R616Q | Missense Mutation (SNP) | VAF 93/191 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99650731; called by muse, mutect2, varscan2
- BRDT | c.917T>C p.L306P | Missense Mutation (SNP) | VAF 138/350 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1008515617; called by muse, mutect2
- BRI3BP | c.45_47dup p.L25dup | In Frame Ins (INS) | VAF 20/110 reads (18%) | catalogued as rs1555215957; called by mutect2, varscan2
- BRMS1 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 102/232 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.209); catalogued as COSV100240136; called by muse, mutect2, varscan2
- BRPF1 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs971945646, COSV57408120; called by muse, mutect2, varscan2
- BRWD1 | c.5104G>A p.V1702M | Missense Mutation (SNP) | VAF 124/318 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs980590601; called by muse, mutect2
- BSG | c.949C>A p.R317S | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61077707; called by muse, mutect2, varscan2
- BSN | c.269G>A p.R90K | Missense Mutation (SNP) | VAF 127/319 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.366); catalogued as rs559032448, COSV56527067; called by muse, mutect2, varscan2
- BSN | c.5009C>T p.T1670I | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1022359141; called by muse, mutect2, varscan2
- BSX | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 111/309 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.305); catalogued as rs913951255; called by muse, mutect2, varscan2
- BTBD11 | c.2620A>G p.K874E (on ENST00000280758 / NM_001018072.2; = p.K411E on NM_001017523.2) | Missense Mutation (SNP) | VAF 16/269 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.444); catalogued as rs1190922935; called by muse, mutect2
- BUB1 | c.1310C>A p.S437Y | Missense Mutation (SNP) | VAF 157/348 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV57061159; called by muse, mutect2, varscan2
- BUB1B | c.35+1G>A p.X12_splice | Splice Site (SNP) | VAF 85/200 reads (43%) | catalogued as rs1044124520, COSV55012571; called by muse, mutect2, varscan2
- C11orf58 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 89/233 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV99930419; called by muse, mutect2, varscan2
- C12orf40 | c.1321C>T p.Q441* | Nonsense Mutation (SNP) | VAF 99/326 reads (30%) | catalogued as rs761077326; called by muse, mutect2, varscan2
- C12orf71 | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 52/83 reads (63%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs746338558; called by muse, mutect2, varscan2
- C16orf46 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 95/248 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55152598; called by muse, mutect2, varscan2
- C16orf54 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as rs535090241, COSV61476926; called by muse, mutect2, varscan2
- C16orf92 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.942); catalogued as rs373854157; called by muse, varscan2
- C16orf96 | c.3120G>T p.E1040D | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.131); catalogued as rs767815692; called by muse, mutect2, varscan2
- C1QTNF8 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.211); catalogued as rs779102043; called by muse, mutect2, varscan2
- C1orf159 | c.277G>A p.A93T (on ENST00000379339 / NM_001330306.2; = p.A57T on NM_017891.5) | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.467); catalogued as rs748326484, COSV53883934; called by muse, mutect2, varscan2
- C1orf216 | c.656G>T p.R219M | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV52054334, COSV99231479; called by muse, mutect2, varscan2
- C21orf91 | c.665-1G>T p.X222_splice | Splice Site (SNP) | VAF 69/226 reads (31%) | catalogued as rs1434515249; called by muse, mutect2, varscan2
- C2CD3 | c.4126G>A p.E1376K | Missense Mutation (SNP) | VAF 77/199 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1284226086; called by muse, mutect2, varscan2
- C2CD3 | c.2416C>T p.H806Y | Missense Mutation (SNP) | VAF 99/279 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as rs1303677178; called by muse, varscan2
- C2CD3 | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.736); catalogued as COSV58090814; called by muse, mutect2
- C2orf81 | c.1567C>A p.L523I | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs563756097, COSV51763620; called by muse, varscan2
- C2orf88 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 31/576 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as rs1487086188; called by muse, mutect2
- C3 | c.2024T>A p.L675H | Missense Mutation (SNP) | VAF 107/307 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs761568524; called by muse, mutect2, varscan2
- C3 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55570775; called by muse, mutect2, varscan2
- C3orf18 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 121/291 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs757932616; called by muse, mutect2, varscan2
- C4BPB | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 131/306 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs781647739; called by muse, mutect2, varscan2
- C4orf45 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 184/358 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1381313614, COSV71701119; called by muse, mutect2, varscan2
- C5orf52 | c.321G>A p.E107= | Splice Region (SNP) | VAF 118/328 reads (36%) | catalogued as rs1234417294; called by muse, mutect2, varscan2
- C6orf120 | c.137A>G p.Q46R | Missense Mutation (SNP) | VAF 56/101 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.106); catalogued as rs755376773; called by muse, mutect2, varscan2
- C7orf31 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 136/296 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.91); catalogued as rs1360307688, COSV52216782; called by muse, varscan2
- C8B | c.164G>T p.S55I | Missense Mutation (SNP) | VAF 142/342 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs144586148; called by muse, mutect2, varscan2
- CA3 | c.227G>A p.R76K | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT tolerated (0.98); PolyPhen benign (0.076); catalogued as rs926125576, COSV53409199; called by muse, mutect2, varscan2
- CABP1 | c.939+6G>A | Splice Region (SNP) | VAF 64/141 reads (45%) | catalogued as rs777033084; called by muse, mutect2, varscan2
- CACHD1 | c.2031G>A p.M677I | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.48); catalogued as rs1159220222; called by muse, mutect2
- CACNA1B | c.3809C>T p.A1270V | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.842); catalogued as COSV53122580; called by muse, mutect2, varscan2
- CACNA1B | c.6661C>T p.P2221S | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs1384021278; called by muse, varscan2
- CACNA1C | c.4706C>G p.A1569G | Missense Mutation (SNP) | VAF 176/419 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV100217102; called by muse, mutect2, varscan2
- CACNA1H | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as rs778637721, COSV61999184; called by muse, mutect2, varscan2
- CACNA1S | c.4406C>T p.A1469V | Missense Mutation (SNP) | VAF 135/305 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1246058295; called by muse, mutect2, varscan2
- CACNA1S | c.3083C>T p.A1028V | Missense Mutation (SNP) | VAF 81/215 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs751604155, COSV62936777; called by muse, mutect2, varscan2
- CACNA1S | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as rs370861322; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D1 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 152/353 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.232); catalogued as rs373911809; called by muse, mutect2, varscan2
- CACUL1 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs765904848; called by muse, varscan2
- CADM2 | c.599C>T p.A200V (on ENST00000407528 / NM_001167674.2; = p.A202V on NM_153184.4) | Missense Mutation (SNP) | VAF 96/242 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs934666245, COSV67371559; called by muse, varscan2
- CALHM4 | c.541C>T p.H181Y (on ENST00000368596 / NM_001366078.1; = p.H38Y on NM_001256887.3) | Missense Mutation (SNP) | VAF 92/256 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as rs1440017584; called by muse, mutect2, varscan2
- CALN1 | c.55C>T p.R19* (on ENST00000329008 / NM_001017440.3; = p.R61* on NM_031468.4) | Nonsense Mutation (SNP) | VAF 129/281 reads (46%) | catalogued as COSV100204732; called by muse, mutect2, varscan2
- CAMK1 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 82/214 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.881); catalogued as rs540971111; called by muse, mutect2, varscan2
- CAMKK1 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 136/293 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs780001304; called by muse, mutect2, varscan2
- CAND1 | c.2960C>T p.T987M | Missense Mutation (SNP) | VAF 138/373 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs751453121, COSV73389530; called by muse, mutect2, varscan2
- CAP1 | c.587A>G p.Y196C | Missense Mutation (SNP) | VAF 173/411 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs1315166635; called by muse, mutect2, varscan2
- CAPN1 | c.1564G>A p.V522M | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.167); catalogued as COSV54198728; called by muse, varscan2
- CAPN15 | c.2441G>A p.G814E | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT tolerated (0.85); PolyPhen benign (0.118); catalogued as rs777073285, COSV54836870; called by muse, mutect2, varscan2
- CAPN15 | c.2726C>T p.P909L | Missense Mutation (SNP) | VAF 80/155 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1158940740; called by muse, mutect2, varscan2
- CAPZA3 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 94/123 reads (76%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.562); catalogued as COSV56851099, COSV99856026; called by muse, mutect2, varscan2
- CARD11 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 83/211 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62718328; called by muse, mutect2, varscan2
- CARD6 | c.69A>T p.Q23H | Missense Mutation (SNP) | VAF 167/431 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs959728906; called by muse, mutect2, varscan2
- CARMIL3 | c.770+1G>T p.X257_splice | Splice Site (SNP) | VAF 77/184 reads (42%) | catalogued as COSV57726628; called by muse, varscan2
- CASD1 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 42/400 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51975003; called by muse, mutect2, varscan2
- CASP10 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 156/352 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV53778252; called by muse, mutect2, varscan2
- CASP4 | c.801G>T p.W267C | Missense Mutation (SNP) | VAF 74/317 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV67744530; called by muse, mutect2, varscan2
- CASP5 | c.1216T>A p.S406T | Missense Mutation (SNP) | VAF 199/364 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs778085364; called by muse, mutect2, varscan2
- CASP8AP2 | c.3075A>G p.I1025M | Missense Mutation (SNP) | VAF 112/287 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1289194180; called by muse, mutect2, varscan2
- CASQ2 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 124/284 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749547712, CM067984, COSV54771908; ClinVar: uncertain significance; called by muse, varscan2
- CASS4 | c.1750G>T p.G584* | Nonsense Mutation (SNP) | VAF 161/401 reads (40%) | catalogued as COSV100824901; called by muse, mutect2, varscan2
- CASZ1 | c.1477C>A p.L493I | Missense Mutation (SNP) | VAF 95/241 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); catalogued as COSV59735015; called by muse, mutect2, varscan2
- CATSPER1 | c.98G>T p.R33M | Missense Mutation (SNP) | VAF 86/228 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100375954; called by muse, mutect2, varscan2
- CAVIN1 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 93/222 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1198309615, COSV63812269; called by muse, mutect2, varscan2
- CBFA2T2 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 165/370 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs780878677; called by muse, mutect2, varscan2
- CBFA2T3 | c.1404C>T p.D468= | Splice Region (SNP) | VAF 53/149 reads (36%) | catalogued as rs1369543012, COSV99242323; called by muse, mutect2, varscan2
- CBL | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 182/437 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50633001, COSV50661418; called by muse, mutect2, varscan2
- CC2D2A | c.287C>A p.A96E | Missense Mutation (SNP) | VAF 29/534 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.494); catalogued as COSV101052610; called by muse, mutect2
- CC2D2A | c.2648A>G p.Y883C | Missense Mutation (SNP) | VAF 88/202 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.773); catalogued as COSV67504313; called by muse, varscan2
- CC2D2B | c.885T>G p.F295L | Missense Mutation (SNP) | VAF 93/283 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60359256; called by muse, mutect2
- CCAR1 | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 100/288 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99771406; called by muse, mutect2, varscan2
- CCDC113 | c.101+1G>A p.X34_splice | Splice Site (SNP) | VAF 42/100 reads (42%) | catalogued as rs1298565482; called by muse, mutect2, varscan2
- CCDC141 | c.1782G>T p.Q594H | Missense Mutation (SNP) | VAF 187/439 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV55376553; called by muse, mutect2, varscan2
- CCDC141 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 137/375 reads (37%) | catalogued as COSV69459291; called by muse, mutect2, varscan2
- CCDC141 | c.396A>T p.E132D | Missense Mutation (SNP) | VAF 84/270 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.042); catalogued as COSV101330501; called by muse, mutect2, varscan2
- CCDC149 | c.785G>A p.S262N | Missense Mutation (SNP) | VAF 79/376 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1165130850; called by muse, mutect2, varscan2
- CCDC178 | c.1594G>A p.G532S | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.276); catalogued as rs551885502, COSV55771575; called by muse, mutect2, varscan2
- CCDC191 | c.4C>T p.L2F | Missense Mutation (SNP) | VAF 157/326 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.595); catalogued as rs1214631969; called by muse, mutect2, varscan2
- CCDC22 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 109/136 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200954122; called by muse, mutect2, varscan2
- CCDC60 | c.273G>T p.E91D | Missense Mutation (SNP) | VAF 218/512 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100555383; called by muse, mutect2, varscan2
- CCDC62 | c.2036dup p.N679Kfs*51 | Frame Shift Ins (INS) | VAF 166/559 reads (30%) | catalogued as rs1053262354; called by mutect2, varscan2
- CCDC63 | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 108/299 reads (36%) | catalogued as COSV57528141; called by muse, varscan2
- CCDC73 | c.836A>T p.D279V | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs758318866; called by muse, varscan2
- CCDC8 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as COSV56772127; called by muse, mutect2, varscan2
- CCDC80 | c.2770C>T p.H924Y | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52817744; called by muse, mutect2, varscan2
- CCDC80 | c.1508G>A p.S503N | Missense Mutation (SNP) | VAF 73/192 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs151141158; called by muse, mutect2, varscan2
- CCDC82 | c.82C>T p.R28* | Nonsense Mutation (SNP) | VAF 150/367 reads (41%) | catalogued as rs747223490; called by muse, mutect2
- CCDC88C | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 99/245 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs747903318; called by muse, mutect2, varscan2
- CCDC9B | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 101/246 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs757434009; called by muse, mutect2, varscan2
- CCNB2 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 95/257 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.818); catalogued as rs750922699, COSV55595002; called by muse, mutect2, varscan2
- CCNB3 | c.3235G>A p.V1079M | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.165); catalogued as rs781908510, COSV99329628; called by muse, mutect2, varscan2
- CCNE2 | c.422T>C p.M141T | Missense Mutation (SNP) | VAF 130/315 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1281695188; called by muse, mutect2, varscan2
- CCNYL1 | c.346C>T p.L116F (on ENST00000295414 / NM_001330218.2; = p.L46F on NM_152523.2) | Missense Mutation (SNP) | VAF 124/339 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.56); catalogued as COSV54939383; called by muse, varscan2
- CCP110 | c.1169T>C p.I390T | Missense Mutation (SNP) | VAF 96/233 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761214278; called by muse, mutect2, varscan2
- CCT8 | c.679A>G p.T227A | Missense Mutation (SNP) | VAF 156/389 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs745786262; called by muse, mutect2, varscan2
- CCZ1B | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 102/259 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100367754; called by mutect2, varscan2
- CCZ1B | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 106/354 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs140768534; called by muse, varscan2
- CD163 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV63131365; called by muse, varscan2
- CD180 | c.875C>A p.T292N | Missense Mutation (SNP) | VAF 178/457 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1400837926, COSV56518184; called by muse, mutect2, varscan2
- CD1D | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 129/291 reads (44%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs767850265, COSV100939534, COSV63809237; called by muse, mutect2, varscan2
- CD1E | c.989A>G p.K330R | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV63770961; called by muse, mutect2
- CD248 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 111/267 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.251); catalogued as rs770613673, COSV60938113; called by muse, mutect2, varscan2
- CD2AP | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 126/384 reads (33%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.948); catalogued as rs763364546; called by muse, mutect2, varscan2
- CD300A | c.521T>A p.V174E | Missense Mutation (SNP) | VAF 123/303 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.145); catalogued as COSV60411105; called by muse, mutect2, varscan2
- CD300A | c.661A>G p.K221E | Missense Mutation (SNP) | VAF 146/411 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs993348953; called by muse, mutect2, varscan2
- CD300LD | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.046); catalogued as COSV60083296; called by muse, mutect2, varscan2
- CD300LG | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 104/301 reads (35%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.536); catalogued as rs184299869; called by muse, mutect2, varscan2
- CD33 | c.599C>T p.T200I | Missense Mutation (SNP) | VAF 75/224 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.165); catalogued as rs1274826359, COSV51801417; called by muse, mutect2, varscan2
- CD44 | c.921C>A p.T307= | Splice Region (SNP) | VAF 112/287 reads (39%) | catalogued as COSV99555955; called by muse, mutect2, varscan2
- CD80 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 118/261 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.755); catalogued as rs1326386326; called by muse, mutect2, varscan2
- CD80 | c.431C>T p.T144I | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.081); catalogued as rs1400058733; called by muse, mutect2, varscan2
- CD93 | c.283A>T p.I95F | Missense Mutation (SNP) | VAF 117/267 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV55666619; called by muse, mutect2, varscan2
- CDC20B | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 92/254 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); catalogued as rs1193145686, COSV57049480; called by muse, varscan2
- CDC25B | c.458C>T p.P153L (on ENST00000245960 / NM_021873.3; = p.P139L on NM_004358.4) | Missense Mutation (SNP) | VAF 119/302 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs775666911, COSV99847854; called by muse, varscan2
- CDC25C | c.1012G>A p.G338R | Missense Mutation (SNP) | VAF 56/230 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772712949; called by muse, mutect2, varscan2
- CDC26 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 137/420 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs780745708, COSV65252945, COSV65252961; called by muse, varscan2
- CDC27 | c.1170+2T>A p.X390_splice | Splice Site (SNP) | VAF 108/284 reads (38%) | catalogued as rs75932008, COSV50630796; called by muse, varscan2
- CDC40 | c.727+6A>G | Splice Region (SNP) | VAF 55/209 reads (26%) | catalogued as rs1478880644; called by muse, mutect2, varscan2
- CDC42BPA | c.1451G>A p.S484N | Missense Mutation (SNP) | VAF 154/410 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1301039758; called by muse, mutect2, varscan2
- CDC42BPB | c.4744A>G p.M1582V | Missense Mutation (SNP) | VAF 77/223 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1432873707; called by muse, mutect2, varscan2
- CDC42BPG | c.4069C>T p.R1357W | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480597328, COSV100712162; called by muse, mutect2, varscan2
- CDCA5 | c.405C>A p.D135E | Missense Mutation (SNP) | VAF 81/179 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as rs771575347; called by muse, mutect2, varscan2
- CDH15 | c.748C>A p.L250I | Missense Mutation (SNP) | VAF 77/205 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.305); catalogued as COSV99228722; called by mutect2, varscan2
- CDH16 | c.1913C>T p.A638V | Missense Mutation (SNP) | VAF 77/185 reads (42%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs1243920228; called by muse, mutect2, varscan2
- CDH23 | c.3643C>T p.R1215C | Missense Mutation (SNP) | VAF 122/327 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758254641; called by muse, mutect2, varscan2
- CDH4 | c.155A>G p.E52G | Missense Mutation (SNP) | VAF 177/422 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV64677889; called by muse, mutect2, varscan2
- CDH5 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as rs369961093; called by muse, varscan2
- CDH6 | c.644-2A>G p.X215_splice | Splice Site (SNP) | VAF 69/158 reads (44%) | catalogued as COSV54063445; called by muse, mutect2, varscan2
- CDH7 | c.727T>C p.S243P | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV100542803; called by muse, mutect2, varscan2
- CDH9 | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 101/272 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV50252202, COSV50339420, COSV50368967; called by muse, mutect2, varscan2
- CDHR2 | c.1918G>A p.G640R | Missense Mutation (SNP) | VAF 83/211 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1172553014; called by muse, mutect2, varscan2
- CDHR5 | c.293G>A p.C98Y | Missense Mutation (SNP) | VAF 101/263 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs756678322; called by muse, mutect2, varscan2
- CDK5RAP3 | c.909+1G>A p.X303_splice | Splice Site (SNP) | VAF 96/219 reads (44%) | catalogued as COSV58115282; called by muse, mutect2, varscan2
- CDK5RAP3 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 113/276 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1021511395; called by muse, mutect2, varscan2
- CDK9 | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 109/258 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs562638413; called by muse, mutect2, varscan2
- CDKN1A | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 137/271 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV55191854; called by muse, mutect2, varscan2
- CDKN1B | c.228G>A p.W76* | Nonsense Mutation (SNP) | VAF 62/116 reads (53%) | catalogued as COSV57430342; called by muse, mutect2, varscan2
- CDKN2A | c.206A>G p.E69G | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs372670098, CM065061, COSV58725369; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CDS2 | c.530-1G>A p.X177_splice | Splice Site (SNP) | VAF 60/185 reads (32%) | catalogued as rs1375160322; called by muse, mutect2, varscan2
- CDYL | c.1588A>G p.T530A (on ENST00000328908 / NM_001368125.1; = p.T476A on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/302 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.245); catalogued as COSV59359126; called by muse, mutect2, varscan2
- CEACAM16 | c.992G>A p.G331D | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs528186083, COSV69187685; called by muse, mutect2, varscan2
- CECR2 | c.1586G>A p.R529K (on ENST00000342247 / NM_001290047.2; = p.R346K on NM_001290046.1) | Missense Mutation (SNP) | VAF 133/182 reads (73%) | SIFT deleterious (0.05); PolyPhen benign (0.085); catalogued as rs1360452688; called by muse, mutect2, varscan2
- CELA2A | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 118/291 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.678); catalogued as rs369322739, COSV100657604; called by muse, mutect2, varscan2
- CELA2A | c.172T>C p.C58R | Missense Mutation (SNP) | VAF 115/262 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1421149926; called by muse, mutect2, varscan2
- CELSR3 | c.1524C>A p.S508R | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as rs752662158; called by muse, mutect2, varscan2
- CEMIP | c.1505G>A p.G502E | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749492356; called by muse, mutect2, varscan2
- CEMIP2 | c.2308G>A p.V770I | Missense Mutation (SNP) | VAF 157/404 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs1179360217; called by muse, mutect2, varscan2
- CENPC | c.2243T>C p.L748S | Missense Mutation (SNP) | VAF 144/487 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752910021; called by muse, mutect2, varscan2
- CENPC | c.290T>C p.L97P | Missense Mutation (SNP) | VAF 74/388 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); catalogued as rs1265528061; called by muse, mutect2, varscan2
- CENPC | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 126/317 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1208008096; called by muse, mutect2, varscan2
- CENPF | c.1866G>A p.W622* | Nonsense Mutation (SNP) | VAF 139/552 reads (25%) | catalogued as COSV65273066, COSV65273078; called by muse, mutect2, varscan2
- CENPF | c.6040G>A p.E2014K | Missense Mutation (SNP) | VAF 163/421 reads (39%) | SIFT tolerated (0.86); PolyPhen benign (0.015); catalogued as COSV100871666; called by muse, mutect2, varscan2
- CENPP | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 121/304 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1275495316; called by muse, mutect2, varscan2
- CEP135 | c.2369G>A p.R790H | Missense Mutation (SNP) | VAF 43/298 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs149552948; called by muse, mutect2, varscan2
- CEP162 | c.757A>G p.N253D | Missense Mutation (SNP) | VAF 126/297 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1562076065, COSV57620302; called by muse, varscan2
- CEP170B | c.1147G>A p.E383K (on ENST00000453495; = p.E312K on NM_015005.3) | Missense Mutation (SNP) | VAF 74/186 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.349); catalogued as rs1158661451; called by muse, mutect2
- CEP192 | c.3652C>T p.Q1218* | Nonsense Mutation (SNP) | VAF 50/135 reads (37%) | catalogued as rs1257069617; called by muse, varscan2
- CEP250 | c.6507G>A p.W2169* | Nonsense Mutation (SNP) | VAF 72/156 reads (46%) | catalogued as rs1196672067; called by muse, mutect2, varscan2
- CEP41 | c.968A>G p.H323R | Missense Mutation (SNP) | VAF 108/416 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs782780788, COSV99782932; called by muse, mutect2, varscan2
- CEP97 | c.839T>C p.L280P | Missense Mutation (SNP) | VAF 119/337 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs761683619; called by muse, mutect2, varscan2
- CERK | c.922C>T p.L308F | Missense Mutation (SNP) | VAF 95/260 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.629); catalogued as rs1257794000; called by muse, mutect2, varscan2
- CERT1 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.053); catalogued as rs754735042; called by muse, mutect2, varscan2
- CFAP43 | c.2916C>A p.S972R | Missense Mutation (SNP) | VAF 90/195 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.195); catalogued as COSV99530373; called by muse, mutect2, varscan2
- CFAP54 | c.373T>C p.Y125H | Missense Mutation (SNP) | VAF 22/456 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1348457662; called by muse, mutect2
- CFAP54 | c.5462T>C p.I1821T | Missense Mutation (SNP) | VAF 76/192 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as rs188725606; called by muse, mutect2, varscan2
- CFAP57 | c.1673A>G p.N558S | Missense Mutation (SNP) | VAF 104/262 reads (40%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs769988170; called by muse, mutect2, varscan2
- CFAP65 | c.3659C>T p.A1220V | Missense Mutation (SNP) | VAF 121/317 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs1361556624; called by muse, mutect2, varscan2
- CFAP69 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 106/282 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.647); catalogued as rs1465190586, COSV60186598; called by muse, mutect2, varscan2
- CFAP69 | c.2726C>T p.T909M | Missense Mutation (SNP) | VAF 133/291 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs747560061; called by muse, varscan2
- CFAP91 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 89/253 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145277027; called by muse, mutect2, varscan2
- CFAP92 | c.1511G>C p.G504A | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101565844; called by muse, mutect2, varscan2
- CFAP94 | c.2129C>T p.T710I (on ENST00000320267 / NM_001352064.2; = p.T716I on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs765666060; called by muse, mutect2, varscan2
- CFAP97 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 209/504 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as COSV57110774; called by muse, mutect2
- CFHR3 | c.614-3C>T | Splice Region (SNP) | VAF 41/128 reads (32%) | catalogued as rs1386509962, COSV100807510; called by muse, mutect2, varscan2
- CFHR4 | c.691C>T p.P231S (on ENST00000367416 / NM_001201551.2; = p.P232S on NM_001201550.3) | Missense Mutation (SNP) | VAF 114/282 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as rs769569814; called by muse, mutect2, varscan2
- CFL2 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 185/468 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV53312120; called by muse, mutect2, varscan2
- CGB2 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.92); catalogued as rs935606172; called by muse, mutect2, varscan2
- CHAC1 | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV71435977; called by muse, mutect2, varscan2
- CHD5 | c.4973G>A p.S1658N | Missense Mutation (SNP) | VAF 109/234 reads (47%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV99315590; called by muse, mutect2, varscan2
- CHD5 | c.3214G>A p.G1072S | Missense Mutation (SNP) | VAF 121/275 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52420248; called by muse, mutect2, varscan2
- CHD6 | c.7405A>G p.M2469V | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.366); catalogued as rs759786562, COSV64694245; called by muse, mutect2, varscan2
- CHD6 | c.4067C>T p.T1356M | Missense Mutation (SNP) | VAF 98/232 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs779881509; called by muse, mutect2, varscan2
- CHD7 | c.2956A>G p.M986V | Missense Mutation (SNP) | VAF 72/195 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs764345519; called by muse, mutect2, varscan2
- CHD7 | c.8321G>A p.G2774D | Missense Mutation (SNP) | VAF 108/247 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV71106994; called by muse, mutect2, varscan2
- CHD8 | c.7276C>T p.L2426F (on ENST00000646647 / NM_001170629.2; = p.L2147F on NM_020920.4) | Missense Mutation (SNP) | VAF 98/283 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs770679545; called by muse, mutect2, varscan2
- CHD8 | c.1036C>T p.Q346* (on ENST00000646647 / NM_001170629.2; = p.Q67* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 87/236 reads (37%) | catalogued as rs1555318278; called by muse, mutect2, varscan2
- CHD9 | c.4579G>T p.D1527Y | Missense Mutation (SNP) | VAF 109/326 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54608665; called by muse, mutect2, varscan2
- CHEK1 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 98/256 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1363144435; called by muse, mutect2, varscan2
- CHGB | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 100/240 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV66761361; called by muse, mutect2, varscan2
- CHM | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 142/164 reads (87%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100753345; called by muse, mutect2, varscan2
- CHML | c.1847T>C p.I616T | Missense Mutation (SNP) | VAF 153/335 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs766614640; called by muse, mutect2, varscan2
- CHMP1B | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 85/246 reads (35%) | catalogued as rs1007245929; called by muse, mutect2, varscan2
- CHPF | c.2068C>T p.R690C | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs376924121; called by muse, mutect2, varscan2
- CHPT1 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 108/278 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as rs910416069; called by muse, varscan2
- CHRND | c.206T>C p.V69A | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.052); catalogued as rs1483337020; called by muse, mutect2
- CHRNG | c.351C>A p.N117K | Missense Mutation (SNP) | VAF 71/188 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV67315638; called by muse, mutect2, varscan2
- CIAO2A | c.290-1G>T p.X97_splice | Splice Site (SNP) | VAF 78/189 reads (41%) | catalogued as COSV55538208; called by muse, mutect2, varscan2
- CIBAR1 | c.330+2T>A p.X110_splice | Splice Site (SNP) | VAF 113/364 reads (31%) | catalogued as COSV100844691; called by muse, mutect2, varscan2
- CIC | c.1546G>T p.G516W | Missense Mutation (SNP) | VAF 115/237 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99359951; called by muse, mutect2, varscan2
- CIDEA | c.501G>T p.K167N | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57601256; called by muse, mutect2
- CIP2A | c.2395C>T p.H799Y | Missense Mutation (SNP) | VAF 118/270 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99843258; called by muse, mutect2, varscan2
- CISH | c.144G>T p.E48D (on ENST00000348721 / NM_145071.4; = p.E65D on NM_013324.6) | Missense Mutation (SNP) | VAF 80/195 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as rs768686842, COSV62295289; called by muse, mutect2, varscan2
- CKAP5 | c.3285G>A p.M1095I | Missense Mutation (SNP) | VAF 115/305 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs755221594; called by muse, mutect2, varscan2
- CKLF | c.311C>T p.T104I | Missense Mutation (SNP) | VAF 125/379 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.605); catalogued as rs1313632464; called by muse, mutect2, varscan2
- CLASP2 | c.1966G>T p.D656Y | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as COSV56291409; called by muse, mutect2
- CLCA4 | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 51/233 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); catalogued as rs776593519; called by muse, mutect2, varscan2
- CLCN1 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 24/383 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs889073641, CM110545, COSV58368676; called by muse, mutect2
- CLCN4 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 127/222 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66464930; called by muse, mutect2, varscan2
- CLCN5 | c.1198C>T p.L400F | Missense Mutation (SNP) | VAF 126/162 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1285536666; called by muse, mutect2, varscan2
- CLCNKA | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 111/365 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs371274486, COSV58891325; called by muse, mutect2
- CLDN18 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs746038647; called by muse, mutect2, varscan2
- CLDN19 | c.223+1G>A p.X75_splice | Splice Site (SNP) | VAF 56/157 reads (36%) | catalogued as rs758302356, COSV99591723; called by muse, varscan2
- CLEC12B | c.336G>T p.Q112H | Missense Mutation (SNP) | VAF 69/273 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as COSV100138863; called by muse, mutect2, varscan2
- CLEC7A | c.379T>A p.Y127N (on ENST00000304084 / NM_197947.3; = p.Y81N on NM_022570.5) | Missense Mutation (SNP) | VAF 131/177 reads (74%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV53722471; called by muse, mutect2, varscan2
- CLGN | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 51/81 reads (63%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); catalogued as COSV57776306; called by muse, mutect2, varscan2
- CLINT1 | c.317A>G p.Y106C | Missense Mutation (SNP) | VAF 136/393 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1400128409; called by muse, mutect2, varscan2
- CLMN | c.1660G>A p.D554N | Missense Mutation (SNP) | VAF 98/207 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.477); catalogued as rs186980388; called by muse, mutect2, varscan2
- CLPTM1 | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 156/382 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.05); catalogued as rs750231038; called by muse, mutect2, varscan2
- CLRN3 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150481499; called by muse, mutect2, varscan2
- CLSTN2 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 93/230 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV101515968; called by muse, mutect2, varscan2
- CLUH | c.3487C>T p.R1163W (on ENST00000435359; = p.R1202W on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/324 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758465453; called by muse, mutect2, varscan2
- CLUH | c.1783C>T p.R595C (on ENST00000435359; = p.R633C on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs752140443, COSV101425847; called by mutect2, varscan2
- CMTM7 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV58550453; called by muse, mutect2, varscan2
- CMTR1 | c.233A>G p.E78G | Missense Mutation (SNP) | VAF 90/296 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.086); catalogued as rs775885006; called by muse, mutect2, varscan2
- CMYA5 | c.9253G>A p.E3085K | Missense Mutation (SNP) | VAF 145/369 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs903789330; called by muse, mutect2, varscan2
- CNGA2 | c.1687T>C p.Y563H | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1270792990; called by muse, mutect2
- CNGA3 | c.1807C>T p.R603W | Missense Mutation (SNP) | VAF 150/302 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs769370731, COSV55624881; called by muse, mutect2, varscan2
- CNN1 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 108/248 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs889642307; called by muse, mutect2, varscan2
- CNNM2 | c.1966C>T p.P656S | Missense Mutation (SNP) | VAF 125/304 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.739); catalogued as rs762852231; called by muse, mutect2, varscan2
- CNTN1 | c.1141G>A p.V381M | Missense Mutation (SNP) | VAF 118/311 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs1449057172; called by muse, mutect2, varscan2
- CNTNAP2 | c.2826G>A p.M942I | Missense Mutation (SNP) | VAF 61/291 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs796052380, COSV62218712; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP3 | c.2533C>T p.R845C | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs201642009, COSV52671103; called by muse, mutect2, varscan2
- CNTNAP4 | c.2971T>C p.Y991H | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.929); catalogued as rs770335753; called by muse, mutect2, varscan2
- CNTNAP5 | c.979C>A p.H327N | Missense Mutation (SNP) | VAF 127/315 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.56); catalogued as COSV70474390; called by muse, mutect2, varscan2
- COASY | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772331281; called by muse, varscan2
- COL14A1 | c.5216G>A p.G1739D | Missense Mutation (SNP) | VAF 75/207 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868494212; called by muse, mutect2, varscan2
- COL17A1 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 132/339 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV62229310; called by muse, mutect2, varscan2
- COL19A1 | c.2761C>T p.P921S | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100506444, COSV59591883; called by muse, mutect2, varscan2
- COL24A1 | c.3950C>T p.P1317L | Missense Mutation (SNP) | VAF 80/214 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV65314604; called by muse, mutect2, varscan2
- COL25A1 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 126/308 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs748116911, COSV67658335; called by muse, mutect2, varscan2
- COL3A1 | c.2860G>T p.G954* | Nonsense Mutation (SNP) | VAF 60/170 reads (35%) | catalogued as CM1412656, COSV100482718; called by muse, mutect2, varscan2
- COL4A1 | c.4081C>T p.L1361F | Missense Mutation (SNP) | VAF 26/263 reads (10%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.961); catalogued as rs1249255276, COSV65429080; called by muse, mutect2
- COL4A3 | c.3131C>T p.P1044L | Missense Mutation (SNP) | VAF 109/263 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.691); catalogued as COSV100516797; called by muse, mutect2, varscan2
- COL4A4 | c.4999C>T p.P1667S | Missense Mutation (SNP) | VAF 136/326 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs1218247424; called by muse, mutect2, varscan2
- COL4A4 | c.4021C>A p.P1341T | Missense Mutation (SNP) | VAF 147/353 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.098); catalogued as rs539867676; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.1523G>T p.G508V | Missense Mutation (SNP) | VAF 143/313 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100880650; called by muse, mutect2, varscan2
- COL5A2 | c.2445+2T>C p.X815_splice | Splice Site (SNP) | VAF 66/161 reads (41%) | catalogued as rs1470583919; called by muse, mutect2, varscan2
- COL5A2 | c.1063C>A p.Q355K | Missense Mutation (SNP) | VAF 127/307 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100880944; called by muse, mutect2, varscan2
- COL5A3 | c.3368G>C p.R1123P | Missense Mutation (SNP) | VAF 146/306 reads (48%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as COSV104393346, COSV99320035; called by muse, mutect2, varscan2
- COL6A3 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs1559271365; called by muse, mutect2, varscan2
- COL6A5 | c.3931G>A p.G1311S | Missense Mutation (SNP) | VAF 249/600 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1320871381; called by muse, mutect2, varscan2
- COL6A6 | c.4436G>A p.G1479E | Missense Mutation (SNP) | VAF 112/365 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62022496; called by muse, varscan2
- COL6A6 | c.4689G>T p.Q1563H | Missense Mutation (SNP) | VAF 78/210 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV100649786; called by muse, varscan2
- COL9A1 | c.1682C>A p.P561H | Missense Mutation (SNP) | VAF 149/381 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.922); catalogued as COSV57891836; called by muse, mutect2, varscan2
- COL9A2 | c.955G>T p.G319C | Missense Mutation (SNP) | VAF 92/181 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65607578; called by muse, mutect2, varscan2
- COLGALT2 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 120/310 reads (39%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.928); catalogued as rs779574494; called by muse, varscan2
- COLQ | c.1157G>A p.C386Y | Missense Mutation (SNP) | VAF 112/309 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368575417, CM081217; called by muse, mutect2, varscan2
- COPB1 | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 194/514 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs778841797; called by muse, varscan2
- COPS7B | c.145C>A p.L49M | Missense Mutation (SNP) | VAF 141/361 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.314); catalogued as rs759195293; called by muse, mutect2, varscan2
- COPS8 | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 156/381 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.935); catalogued as COSV62976190; called by muse, mutect2, varscan2
- COQ10A | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.025); catalogued as rs766456659; called by muse, varscan2
- COQ2 | c.142A>G p.T48A | Missense Mutation (SNP) | VAF 63/163 reads (39%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs1442705983; called by muse, mutect2, varscan2
- CORIN | c.2264C>T p.S755F | Missense Mutation (SNP) | VAF 111/274 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs758993145, COSV56691586; called by muse, mutect2, varscan2
- CORO1B | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV100396722, COSV58173358; called by muse, mutect2, varscan2
- CORO2B | c.964C>A p.L322I | Missense Mutation (SNP) | VAF 71/140 reads (51%) | SIFT tolerated (0.66); PolyPhen benign (0.173); catalogued as COSV55954932; called by muse, mutect2, varscan2
- CORO7 | c.1979G>A p.R660H | Missense Mutation (SNP) | VAF 101/207 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs556093901, COSV52032567; called by muse, mutect2, varscan2
- COX16 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 93/297 reads (31%) | catalogued as rs781059799; called by muse, mutect2, varscan2
- COX7A2 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 109/278 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV100034564; called by muse, mutect2, varscan2
- CP | c.463T>C p.Y155H | Missense Mutation (SNP) | VAF 174/386 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV52830265; called by muse, mutect2, varscan2
- CPA3 | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 97/272 reads (36%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.542); catalogued as COSV56045655; called by muse, mutect2, varscan2
- CPA3 | c.875G>T p.S292I | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as rs774430813; called by muse, mutect2, varscan2
- CPAMD8 | c.4733G>A p.G1578D (on ENST00000651564; = p.G1531D on NM_015692.5) | Missense Mutation (SNP) | VAF 76/145 reads (52%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.996); catalogued as rs1266534152; called by muse, mutect2, varscan2
- CPEB2 | c.1927A>G p.T643A | Missense Mutation (SNP) | VAF 82/205 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.341); catalogued as COSV52592422; called by muse, mutect2, varscan2
- CPNE4 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 159/408 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV101456833; called by muse, mutect2, varscan2
- CPNE8 | c.1643C>A p.P548H | Missense Mutation (SNP) | VAF 102/268 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.478); catalogued as COSV58842750; called by muse, mutect2, varscan2
- CPS1 | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 109/243 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1274668236; called by muse, mutect2, varscan2
- CPSF1 | c.4163G>A p.R1388H | Missense Mutation (SNP) | VAF 101/251 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.07); catalogued as rs782413028; called by muse, mutect2, varscan2
- CPSF6 | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 125/306 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as rs1298036161, COSV57013366; called by muse, mutect2, varscan2
- CPT1C | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 112/271 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as rs753309074, COSV54918161; called by muse, mutect2, varscan2
- CPT1C | c.2116G>A p.G706S | Missense Mutation (SNP) | VAF 125/268 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99773776; called by muse, mutect2, varscan2
- CPT2 | c.814C>A p.H272N | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.099); catalogued as COSV53760068; called by muse, mutect2
- CR1 | c.3953A>T p.H1318L | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.048); catalogued as rs758153459; called by muse, mutect2, varscan2
- CR2 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 99/218 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769415969; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRACD | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 163/365 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV51720331; called by muse, mutect2, varscan2
- CRB1 | c.2733T>A p.C911* | Nonsense Mutation (SNP) | VAF 128/301 reads (43%) | catalogued as COSV100957832; called by muse, varscan2
- CRB2 | c.542G>A p.C181Y | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100749552; called by muse, mutect2, varscan2
- CREB3L1 | c.141G>A p.M47I | Missense Mutation (SNP) | VAF 118/320 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs1326982142; called by muse, mutect2, varscan2
- CREBBP | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 140/355 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs763070109, COSV52126181; called by muse, mutect2, varscan2
- CREG1 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 79/247 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.12); catalogued as COSV65148682; called by muse, mutect2, varscan2
- CRIM1 | c.1506G>T p.E502D | Missense Mutation (SNP) | VAF 73/189 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.109); catalogued as COSV54873046; called by muse, mutect2, varscan2
- CRTC3 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as rs1282421822; called by muse, mutect2, varscan2
- CRYBB1 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 209/467 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.16); catalogued as rs767583919, COSV53232665; called by muse, mutect2, varscan2
- CRYZ | c.898G>T p.G300C | Missense Mutation (SNP) | VAF 105/249 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs374694701, COSV100558668, COSV61718681; called by muse, mutect2, varscan2
- CSGALNACT2 | c.805A>G p.R269G | Missense Mutation (SNP) | VAF 128/298 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100989854; called by muse, mutect2, varscan2
- CSMD1 | c.8242G>T p.G2748* (on ENST00000520002; = p.G2747* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 141/318 reads (44%) | catalogued as COSV59350588; called by muse, mutect2, varscan2
- CSMD1 | c.7409G>T p.S2470I (on ENST00000520002; = p.S2469I on NM_033225.6) | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs771496497; called by muse, mutect2, varscan2
- CSMD1 | c.6932G>A p.G2311D (on ENST00000520002; = p.G2310D on NM_033225.6) | Missense Mutation (SNP) | VAF 100/277 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs780060162, COSV59325600; called by muse, mutect2, varscan2
- CSMD1 | c.125C>T p.T42I | Missense Mutation (SNP) | VAF 139/309 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as rs753888235, COSV68223871; called by muse, mutect2, varscan2
- CSMD2 | c.9246G>T p.E3082D | Missense Mutation (SNP) | VAF 68/199 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs898253956; called by muse, mutect2, varscan2
- CSMD2 | c.5881C>T p.P1961S | Missense Mutation (SNP) | VAF 125/287 reads (44%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.521); catalogued as COSV53955461; called by muse, mutect2, varscan2
- CSMD2 | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 84/316 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1375628081, COSV53957195; called by muse, mutect2, varscan2
- CSMD3 | c.6058A>G p.S2020G (on ENST00000297405 / NM_001363185.1; = p.S1916G on NM_052900.3) | Missense Mutation (SNP) | VAF 58/226 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99835216; called by muse, mutect2, varscan2
- CSNK2A2 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 96/286 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1289137648; called by muse, mutect2, varscan2
- CSPP1 | c.3230C>A p.A1077D (on ENST00000676605; = p.A1036D on NM_024790.6) | Missense Mutation (SNP) | VAF 121/312 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV104385232; called by muse, mutect2, varscan2
- CSRNP3 | c.1082C>T p.T361M | Missense Mutation (SNP) | VAF 102/322 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs543669496, COSV58775683; called by muse, varscan2
- CSRNP3 | c.1657A>G p.I553V | Missense Mutation (SNP) | VAF 117/321 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58781221; called by muse, mutect2, varscan2
- CST1 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 32/98 reads (33%) | catalogued as rs756924682; called by mutect2, varscan2
- CST8 | c.179G>A p.S60N | Missense Mutation (SNP) | VAF 59/355 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs367622893; called by muse, mutect2, varscan2
- CTCF | c.1570G>A p.A524T | Missense Mutation (SNP) | VAF 97/254 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.414); catalogued as rs767996920, COSV50511527; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTDP1 | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV50009946; called by muse, mutect2, varscan2
- CTNNA3 | c.1424T>C p.V475A | Missense Mutation (SNP) | VAF 147/303 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as rs772179026; called by muse, mutect2, varscan2
- CTNNA3 | c.1241A>T p.Y414F | Missense Mutation (SNP) | VAF 127/341 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.981); catalogued as COSV65623738; called by muse, mutect2, varscan2
- CTNNB1 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 120/360 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV62693008; called by muse, mutect2, varscan2
- CTNNB1 | c.1313T>C p.V438A | Missense Mutation (SNP) | VAF 134/269 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs936090981; called by muse, mutect2, varscan2
- CTNNB1 | c.1784C>T p.T595I | Missense Mutation (SNP) | VAF 68/218 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.393); catalogued as COSV100846299; called by muse, varscan2
- CTNND1 | c.2824G>A p.E942K (on ENST00000399050 / NM_001085458.2; = p.E915K on NM_001331.3) | Missense Mutation (SNP) | VAF 56/247 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); catalogued as rs1025483892; called by muse, varscan2
- CTPS1 | c.1768C>A p.H590N | Missense Mutation (SNP) | VAF 83/251 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV101009288; called by muse, mutect2, varscan2
- CTSW | c.388T>C p.F130L | Missense Mutation (SNP) | VAF 86/220 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1478945709; called by muse, mutect2, varscan2
- CTSZ | c.374A>T p.D125V | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99413560; called by muse, mutect2, varscan2
- CTTNBP2 | c.3856C>T p.R1286* | Nonsense Mutation (SNP) | VAF 93/208 reads (45%) | catalogued as rs561305383, COSV50390648; called by muse, varscan2
- CTTNBP2NL | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 108/367 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs757311485; called by muse, mutect2, varscan2
- CUBN | c.3397A>T p.I1133F | Missense Mutation (SNP) | VAF 103/288 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs780288882; called by muse, mutect2, varscan2
- CUBN | c.2517A>T p.E839D | Missense Mutation (SNP) | VAF 139/316 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.11); catalogued as COSV100912041; called by muse, mutect2, varscan2
- CUEDC2 | c.594+4T>A | Splice Region (SNP) | VAF 69/148 reads (47%) | catalogued as rs1565236370; called by muse, mutect2, varscan2
- CUL3 | c.1972A>G p.I658V | Missense Mutation (SNP) | VAF 90/249 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV52363870; called by muse, mutect2
- CUL9 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 144/364 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs748263558, COSV52731616; called by muse, mutect2, varscan2
- CUX1 | c.2966G>T p.S989I | Missense Mutation (SNP) | VAF 91/232 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52895918; called by muse, mutect2, varscan2
- CUZD1 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 96/242 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1263432261; called by muse, varscan2
- CXCR4 | c.548G>A p.R183K | Missense Mutation (SNP) | VAF 95/269 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV54013252; called by muse, mutect2, varscan2
- CXXC5 | c.885A>T p.K295N | Missense Mutation (SNP) | VAF 117/279 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56793263; called by muse, mutect2, varscan2
- CYBRD1 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 130/332 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377410616; called by muse, mutect2, varscan2
- CYLC1 | c.940A>G p.K314E | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV61410141; called by muse, mutect2
- CYP11A1 | c.596G>A p.S199N | Missense Mutation (SNP) | VAF 97/282 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs1221628165; called by muse, mutect2, varscan2
- CYP11B1 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 105/309 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV52828558; called by muse, mutect2, varscan2
- CYP11B1 | c.24G>T p.E8D | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52825070; called by muse, mutect2, varscan2
- CYP2C8 | c.386C>A p.T129K | Missense Mutation (SNP) | VAF 196/441 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs1326941019; called by muse, mutect2, varscan2
- CYP2W1 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 77/197 reads (39%) | catalogued as COSV100417387; called by muse, mutect2, varscan2
- CYP4A22 | c.789A>T p.T263= | Splice Region (SNP) | VAF 77/209 reads (37%) | catalogued as rs1163125822; called by muse, mutect2, varscan2
- CYP4B1 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.025); catalogued as rs756688395, COSV54726316; called by muse, mutect2, varscan2
- CYP4F12 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.078); catalogued as COSV61174674; called by muse, mutect2, varscan2
- CYSLTR2 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 47/261 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99935430; called by muse, mutect2, varscan2
- CYSRT1 | c.506G>A p.C169Y (on ENST00000409414; = p.C129Y on NM_199001.5) | Missense Mutation (SNP) | VAF 79/197 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1564410269; called by muse, mutect2, varscan2
- CYTH3 | c.1079G>A p.R360Q (on ENST00000396741; = p.R359Q on NM_004227.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 126/288 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs371624575, COSV60363215; called by muse, mutect2, varscan2
- DAB1 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 87/368 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59727031; called by muse, mutect2, varscan2
- DAGLA | c.118C>T p.L40F | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1373594098; called by muse, mutect2, varscan2
- DAPK1 | c.3350C>T p.A1117V | Missense Mutation (SNP) | VAF 103/309 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100801312; called by muse, mutect2, varscan2
- DBF4 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 88/290 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1221788934, COSV99719483, COSV99719540; called by muse, varscan2
- DCAF1 | c.1417G>A p.V473I | Missense Mutation (SNP) | VAF 179/424 reads (42%) | SIFT tolerated (0.92); PolyPhen probably damaging (0.931); catalogued as rs782013479; called by muse, mutect2, varscan2
- DCAF4 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 125/336 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1567328994, COSV62320696; called by muse, mutect2, varscan2
- DCAF6 | c.119G>A p.R40K | Missense Mutation (SNP) | VAF 102/394 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.699); catalogued as COSV56581749; called by muse, mutect2, varscan2
- DCAF6 | c.2378A>T p.E793V (on ENST00000312263 / NM_001349778.1; = p.E813V on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs751434646; called by muse, mutect2
- DCAF8L1 | c.568T>C p.Y190H | Missense Mutation (SNP) | VAF 89/105 reads (85%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV71595437; called by muse, mutect2, varscan2
- DCAF8L2 | c.617A>G p.Y206C | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs753453586; called by muse, mutect2, varscan2
- DCHS1 | c.8200G>A p.D2734N | Missense Mutation (SNP) | VAF 90/199 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100197864; called by muse, mutect2, varscan2
- DCST1 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 84/239 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs775679292, COSV55058740; called by muse, mutect2, varscan2
- DCST1 | c.1201C>T p.H401Y | Missense Mutation (SNP) | VAF 166/382 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as rs1425831229; called by muse, mutect2, varscan2
- DCST2 | c.564G>A p.W188* | Nonsense Mutation (SNP) | VAF 114/283 reads (40%) | catalogued as rs1027954959; called by muse, mutect2, varscan2
- DCTN1 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 153/425 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1381488388; called by muse, mutect2, varscan2
- DCUN1D1 | c.182A>T p.D61V | Missense Mutation (SNP) | VAF 130/325 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53046457; called by muse, mutect2, varscan2
- DDC | c.1143T>C p.H381= | Splice Region (SNP) | VAF 87/205 reads (42%) | catalogued as rs756891812, COSV63564458; called by muse, mutect2, varscan2
- DDC | c.656C>A p.A219E | Missense Mutation (SNP) | VAF 136/296 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV63565075; called by muse, varscan2
- DDIAS | c.881A>T p.D294V | Missense Mutation (SNP) | VAF 116/277 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs1439023420; called by muse, varscan2
- DDIAS | c.2953G>A p.V985M | Missense Mutation (SNP) | VAF 127/341 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as rs777807917; called by muse, mutect2, varscan2
- DDR2 | c.1202T>C p.L401P | Missense Mutation (SNP) | VAF 135/296 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1417662811; called by muse, mutect2, varscan2
- DDR2 | c.1676C>A p.P559H | Missense Mutation (SNP) | VAF 137/344 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100906982; called by muse, mutect2, varscan2
- DDX10 | c.1264T>C p.S422P | Missense Mutation (SNP) | VAF 100/362 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59431658; called by muse, mutect2, varscan2
- DDX21 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 105/253 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV62555509; called by muse, mutect2, varscan2
- DDX4 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 136/314 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.91); catalogued as rs1329168156; called by muse, mutect2, varscan2
- DDX42 | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 173/385 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.248); catalogued as rs150380771; called by muse, mutect2, varscan2
- DDX42 | c.1332G>T p.K444N | Missense Mutation (SNP) | VAF 100/425 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV63789570; called by muse, mutect2, varscan2
- DDX58 | c.2443G>A p.A815T | Missense Mutation (SNP) | VAF 100/365 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as rs1211600400; called by muse, mutect2, varscan2
- DDX60 | c.4067C>A p.P1356H | Missense Mutation (SNP) | VAF 102/280 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101190576; called by muse, mutect2, varscan2
- DDX60L | c.2992G>A p.G998R | Missense Mutation (SNP) | VAF 103/272 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52717638, COSV99036209; called by muse, mutect2, varscan2
- DEAF1 | c.1504-1G>A p.X502_splice | Splice Site (SNP) | VAF 125/330 reads (38%) | catalogued as rs1189993385; called by muse, mutect2, varscan2
- DECR1 | c.169T>C p.F57L | Missense Mutation (SNP) | VAF 144/362 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.021); catalogued as rs11548761; called by muse, mutect2, varscan2
- DECR2 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 124/317 reads (39%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.695); catalogued as rs371095028; called by muse, mutect2, varscan2
- DEFB108B | c.59-1G>A p.X20_splice | Splice Site (SNP) | VAF 69/132 reads (52%) | catalogued as rs757881672; called by muse, mutect2, varscan2
- DEFB136 | c.169A>G p.I57V | Missense Mutation (SNP) | VAF 138/342 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0.012); catalogued as rs201142786; called by muse, varscan2
- DEK | c.607G>T p.G203C | Missense Mutation (SNP) | VAF 103/291 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV55237832; called by muse, mutect2, varscan2
- DENND2C | c.656A>T p.Y219F | Missense Mutation (SNP) | VAF 145/314 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101283873; called by muse, mutect2, varscan2
- DENND3 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs1291941080, COSV52807249; called by muse, mutect2, varscan2
- DENND5B | c.3269G>T p.G1090V | Missense Mutation (SNP) | VAF 148/218 reads (68%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs377615526; called by muse, mutect2, varscan2
- DENND5B | c.2514G>A p.M838I | Missense Mutation (SNP) | VAF 184/240 reads (77%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1234324477; called by muse, mutect2, varscan2
- DEPDC1 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 86/210 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1171175301; called by muse, mutect2, varscan2
- DEPDC1B | c.450G>A p.M150I | Missense Mutation (SNP) | VAF 97/230 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs150987461; called by muse, mutect2, varscan2
- DESI1 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 115/246 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs1207493170, COSV54354301; called by muse, mutect2, varscan2
- DEUP1 | c.1129C>T p.L377F | Missense Mutation (SNP) | VAF 122/311 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776866620; called by muse, varscan2
- DEUP1 | c.1188A>C p.K396N | Missense Mutation (SNP) | VAF 86/304 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs756884450, COSV53212038; called by muse, varscan2
- DGCR2 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 194/335 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as rs535152310, COSV54216448; called by muse, mutect2, varscan2
- DGKE | c.332T>A p.I111N | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV99400645; called by muse, varscan2
- DGKE | c.415A>G p.M139V | Missense Mutation (SNP) | VAF 136/386 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1407848078; called by muse, varscan2
- DGKH | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 172/221 reads (78%) | catalogued as rs9566925, COSV54931621; called by muse, mutect2, varscan2
- DGKQ | c.776C>T p.T259M | Missense Mutation (SNP) | VAF 89/257 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1405823467, COSV56619830; called by muse, mutect2, varscan2
- DGKZ | c.2020G>A p.A674T (on ENST00000454345 / NM_001105540.2; = p.A486T on NM_003646.4) | Missense Mutation (SNP) | VAF 100/238 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV58986620; called by muse, mutect2, varscan2
- DHRS7 | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 95/271 reads (35%) | catalogued as rs369616974; called by muse, mutect2, varscan2
- DHX16 | c.2785C>T p.L929F | Missense Mutation (SNP) | VAF 97/238 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as rs755630229; called by muse, mutect2, varscan2
- DHX29 | c.3431+1G>A p.X1144_splice | Splice Site (SNP) | VAF 80/215 reads (37%) | catalogued as COSV52420453; called by muse, mutect2, varscan2
- DHX29 | c.1865A>G p.K622R | Missense Mutation (SNP) | VAF 95/277 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.131); catalogued as rs760608852; called by muse, mutect2, varscan2
- DHX57 | c.1948C>A p.L650M | Missense Mutation (SNP) | VAF 175/458 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54883206; called by muse, mutect2, varscan2
- DIAPH1 | c.1514T>C p.M505T | Missense Mutation (SNP) | VAF 166/411 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.241); catalogued as rs760598547; called by muse, mutect2, varscan2
- DICER1 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 130/352 reads (37%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.519); catalogued as rs1555374798, COSV100601842; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIDO1 | c.5579A>G p.Y1860C | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs773306161; called by muse, mutect2, varscan2
- DIDO1 | c.5314C>T p.P1772S | Missense Mutation (SNP) | VAF 85/230 reads (37%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.03); catalogued as rs151223439; called by muse, mutect2, varscan2
- DIDO1 | c.5147C>T p.A1716V | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1386143803; called by muse, mutect2, varscan2
- DIP2A | c.56A>G p.E19G | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1209851421; called by muse, mutect2, varscan2
- DIPK1A | c.1061G>A p.C354Y | Missense Mutation (SNP) | VAF 103/233 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776715144; called by muse, mutect2, varscan2
- DIRAS2 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 115/272 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65370151; called by muse, mutect2, varscan2
- DIRAS3 | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs149658129; called by muse, varscan2
- DISP1 | c.2347C>T p.L783F | Missense Mutation (SNP) | VAF 84/225 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs1464718896; called by muse, varscan2
- DLEC1 | c.890G>T p.R297M | Missense Mutation (SNP) | VAF 183/431 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as COSV100342174; called by muse, mutect2, varscan2
- DLG1 | c.1898G>A p.G633D | Missense Mutation (SNP) | VAF 122/287 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as COSV58380372; called by muse, mutect2, varscan2
- DLG2 | c.160G>A p.E54K (on ENST00000650630 / NM_001351274.2; = p.E17K on NM_001142699.3) | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101072624, COSV65826078; called by muse, mutect2, varscan2
- DLGAP1 | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 126/294 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs1188288808, COSV59839385; called by muse, mutect2, varscan2
- DLGAP4 | c.1483G>A p.A495T | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as rs1349254717; called by muse, mutect2, varscan2
- DLGAP4 | c.2240C>T p.A747V (on ENST00000339266 / NM_001365621.1; = p.A744V on NM_014902.6) | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as rs1166217825; called by muse, mutect2, varscan2
- DLX5 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 67/242 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as rs376161860; called by muse, mutect2, varscan2
- DMD | c.5586G>T p.K1862N | Missense Mutation (SNP) | VAF 80/99 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63735369; called by muse, mutect2, varscan2
17,026 further variants in this file (9,788 protein-altering or splice-affecting, 3,915 silent, 3,323 other) are not listed here.
